Somatic mutation profile of tumor specimen TCGA-B5-A11G-01A (aliquot TCGA-B5-A11G-01A-13D-A122-09) from TCGA case TCGA-B5-A11G, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IA; Tumor grade: G1; Age at diagnosis: 71.2 years (25,995 days).
Specimen TCGA-B5-A11G-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e2fb5861-05bc-4034-80ab-0f38914ab2d4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B5-A11G-10A (Blood Derived Normal), aliquot TCGA-B5-A11G-10A-01D-A122-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2e658a26-28e6-4c88-a62b-1ff58b6d13eb

The open-access MAF lists 664 somatic variants for this specimen: 510 protein-altering or splice-affecting, 146 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 335, Silent 146, Frame Shift Ins 107, Frame Shift Del 31, Splice Site 15, Splice Region 10, Nonsense Mutation 9, RNA 3, In Frame Del 2, 5'UTR 2, Intron 2, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANKRD11 | c.3309dup p.D1104Rfs*2 | Frame Shift Ins (INS) | VAF 111/282 reads (39%) | catalogued as rs772267579; ClinVar: pathogenic; called by mutect2, varscan2
- ATM | c.3994-1G>T p.X1332_splice | Splice Site (SNP) | VAF 55/136 reads (40%) | catalogued as rs1057516238, COSV104377475, COSV53743982; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ATRX | c.6811A>G p.R2271G | Missense Mutation (SNP) | VAF 228/509 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs122445112, CM057844, COSV64876526; ClinVar: pathogenic; called by muse, mutect2, varscan2
- EP300 | c.4352A>G p.H1451R | Missense Mutation (SNP) | VAF 95/246 reads (39%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV54328613, COSV54328640, COSV54332675; called by muse, mutect2, varscan2
- ERBB2 | c.2033G>A p.R678Q | Missense Mutation (SNP) | VAF 66/155 reads (43%) | hotspot (GDC flag); SIFT tolerated (0.19); PolyPhen benign (0.103); catalogued as rs1057519862, COSV54062926; ClinVar: likely pathogenic / not provided; called by muse, mutect2, varscan2
- FLCN | c.1285dup p.H429Pfs*27 | Frame Shift Ins (INS) | VAF 14/28 reads (50%) | catalogued as rs80338682; ClinVar: pathogenic; called by mutect2, varscan2
- GABRG2 | c.351dup p.A118Cfs*6 | Frame Shift Ins (INS) | VAF 64/189 reads (34%) | catalogued as rs1554097873; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- HSPG2 | c.1219dup p.Q407Pfs*62 | Frame Shift Ins (INS) | VAF 6/20 reads (30%) | catalogued as rs763945561; ClinVar: likely pathogenic; called by mutect2, varscan2
- IVD | c.879dup p.P294Afs*38 (on ENST00000651168; = p.P291Afs*38 on NM_002225.5 and 5 other RefSeq transcripts) | Frame Shift Ins (INS) | VAF 37/112 reads (33%) | catalogued as rs759159766; ClinVar: pathogenic; called by mutect2, varscan2
- LRP2 | c.13139dup p.C4381Mfs*12 | Frame Shift Ins (INS) | VAF 44/118 reads (37%) | catalogued as rs80338754; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- PCDH19 | c.1091dup p.Y366Lfs*10 | Frame Shift Ins (INS) | VAF 18/42 reads (43%) | catalogued as rs758946412; ClinVar: pathogenic; called by mutect2, varscan2
- PIK3CA | c.328_330del p.E110del | In Frame Del (DEL) | VAF 40/129 reads (31%) | hotspot (GDC flag); called by pindel, varscan2
- PTEN | c.968dup p.N323Kfs*2 | Frame Shift Ins (INS) | VAF 70/214 reads (33%) | catalogued as rs121913291; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- RAD50 | c.2801del p.N934Ifs*6 | Frame Shift Del (DEL) | VAF 118/274 reads (43%) | catalogued as rs748536322; ClinVar: pathogenic; called by mutect2, varscan2
- ACE | c.353G>A p.R118H | Missense Mutation (SNP) | VAF 20/27 reads (74%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as rs773121538, COSV52020381; called by muse, mutect2, varscan2
- ACOXL | c.436C>T p.L146F | Missense Mutation (SNP) | VAF 116/263 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs768893329, COSV61324873; called by muse, mutect2, varscan2
- ACVR2A | c.895G>A p.G299R | Missense Mutation (SNP) | VAF 103/254 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54022470; called by muse, mutect2, varscan2
- ACVR2A | c.1310del p.K437Rfs*5 | Frame Shift Del (DEL) | VAF 98/264 reads (37%) | catalogued as rs764719749, COSV104385546; called by mutect2, varscan2
- ADD3 | c.195+2T>C p.X65_splice | Splice Site (SNP) | VAF 65/141 reads (46%) | catalogued as COSV53322358; called by muse, mutect2, varscan2
- ADGRL1 | c.3337C>T p.R1113C (on ENST00000340736 / NM_001008701.3; = p.R1108C on NM_014921.5) | Missense Mutation (SNP) | VAF 83/217 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs778374913, COSV61564705; called by muse, mutect2, varscan2
- AGT | c.1277A>G p.N426S | Missense Mutation (SNP) | VAF 65/181 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.883); catalogued as COSV64184559; called by muse, mutect2, varscan2
- AHCTF1 | c.3667T>A p.S1223T (on ENST00000366508; = p.S1197T on NM_015446.5) | Missense Mutation (SNP) | VAF 64/247 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.921); catalogued as COSV58250110; called by muse, mutect2, varscan2
- AHNAK2 | c.14420A>C p.E4807A | Missense Mutation (SNP) | VAF 44/112 reads (39%) | SIFT tolerated (0.25); PolyPhen benign (0.062); catalogued as COSV60915327; called by muse, mutect2, varscan2
- AK9 | c.3625del p.R1209Gfs*39 | Frame Shift Del (DEL) | VAF 136/392 reads (35%) | catalogued as rs778351035; called by mutect2, pindel, varscan2
- AKAP9 | c.116del p.K39Rfs*17 | Frame Shift Del (DEL) | VAF 47/125 reads (38%) | catalogued as COSV62339755; called by mutect2, varscan2
- ALPK2 | c.1568del p.K523Rfs*15 | Frame Shift Del (DEL) | VAF 105/595 reads (18%) | catalogued as rs1341338515; called by pindel, varscan2
- AMER3 | c.1081G>A p.G361S | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT tolerated (0.26); PolyPhen benign (0.141); catalogued as rs367830628; called by muse, varscan2
- AMPH | c.1391A>G p.E464G | Missense Mutation (SNP) | VAF 48/167 reads (29%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV100341694, COSV57741909; called by muse, varscan2
- ANK3 | c.12310A>G p.S4104G (on ENST00000280772 / NM_001320874.2; = p.S625G on NM_001149.3) | Missense Mutation (SNP) | VAF 88/177 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as COSV55057806; called by muse, mutect2, varscan2
- ANLN | c.3329G>A p.R1110H | Missense Mutation (SNP) | VAF 120/269 reads (45%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.632); catalogued as rs1289306655, COSV56076259; called by muse, mutect2, varscan2
- ANO5 | c.1226A>G p.E409G | Missense Mutation (SNP) | VAF 84/194 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.2); catalogued as COSV61083542; called by muse, varscan2
- APC | c.4747A>G p.M1583V | Missense Mutation (SNP) | VAF 66/161 reads (41%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.977); catalogued as rs753723223, COSV57344589; called by muse, mutect2, varscan2
- APCDD1L | c.1115A>G p.N372S | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV64486354; called by muse, mutect2, varscan2
- APOB | c.696C>T p.T232= | Splice Region (SNP) | VAF 61/176 reads (35%) | catalogued as COSV51926821, COSV51935232; called by muse, mutect2, varscan2
- ARHGAP36 | c.1285C>T p.P429S | Missense Mutation (SNP) | VAF 84/168 reads (50%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.749); catalogued as COSV52266716; called by muse, mutect2, varscan2
- ARHGEF19 | c.469G>A p.A157T | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as rs767352434, COSV54616559; called by muse, mutect2, varscan2
- ARHGEF37 | c.958T>C p.Y320H | Missense Mutation (SNP) | VAF 110/274 reads (40%) | SIFT deleterious (0.05); PolyPhen benign (0.345); catalogued as COSV61368718; called by muse, mutect2, varscan2
- ARID5B | c.1489del p.I497* | Frame Shift Del (DEL) | VAF 67/188 reads (36%) | catalogued as rs201178069; called by mutect2, pindel, varscan2
- ARMC8 | c.496T>A p.Y166N (on ENST00000469044 / NM_001363941.2; = p.Y152N on NM_014154.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 65/146 reads (45%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.969); catalogued as COSV61768458; called by muse, mutect2, varscan2
- ARNT2 | c.136C>T p.R46W | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs140468271, CM141147, COSV57583743; called by muse, mutect2
- ARSJ | c.1216A>G p.T406A | Missense Mutation (SNP) | VAF 76/169 reads (45%) | SIFT tolerated (0.47); PolyPhen benign (0.059); catalogued as COSV59537863; called by muse, mutect2, varscan2
- ASTN2 | c.3424A>G p.S1142G (on ENST00000313400 / NM_001365069.1; = p.S1091G on NM_014010.5) | Missense Mutation (SNP) | VAF 55/132 reads (42%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.22); catalogued as COSV56004644; called by muse, mutect2, varscan2
- ATF7IP | c.2941+2T>A p.X981_splice | Splice Site (SNP) | VAF 158/377 reads (42%) | catalogued as COSV53770815, COSV53776429; called by muse, mutect2, varscan2
- ATG9B | c.293dup p.T99Nfs*50 | Frame Shift Ins (INS) | VAF 12/30 reads (40%) | catalogued as rs770350293; called by mutect2, varscan2
- ATM | c.6318T>A p.N2106K | Missense Mutation (SNP) | VAF 98/216 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.118); catalogued as COSV53743997; called by muse, varscan2
- ATP11B | c.2692T>C p.F898L | Missense Mutation (SNP) | VAF 210/772 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.347); catalogued as COSV60028616; called by muse, varscan2
- ATP2B3 | c.2224A>G p.N742D | Missense Mutation (SNP) | VAF 34/67 reads (51%) | SIFT tolerated (0.85); PolyPhen benign (0.012); catalogued as COSV54847134; called by muse, mutect2, varscan2
- ATP6V1C1 | c.200+2T>C p.X67_splice | Splice Site (SNP) | VAF 225/463 reads (49%) | catalogued as COSV67778027; called by muse, mutect2, varscan2
- ATR | c.4727T>G p.L1576R | Missense Mutation (SNP) | VAF 156/353 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV63386452; called by muse, varscan2
- AXDND1 | c.239T>C p.L80S | Missense Mutation (SNP) | VAF 36/162 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62642614; called by muse, mutect2, varscan2
- B4GALNT1 | c.649A>G p.N217D | Missense Mutation (SNP) | VAF 63/160 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV57542765; called by muse, mutect2, varscan2
- BAG4 | c.254C>T p.A85V | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT tolerated (0.07); PolyPhen benign (0.051); catalogued as COSV54860137; called by muse, mutect2, varscan2
- BCL7C | c.652T>C p.*218Rext*? | Nonstop Mutation (SNP) | VAF 27/74 reads (36%) | catalogued as COSV53063104; called by muse, mutect2, varscan2
- BFAR | c.763dup p.Q255Pfs*7 | Frame Shift Ins (INS) | VAF 51/100 reads (51%) | catalogued as rs781267226; called by mutect2, varscan2
- BOK | c.256C>A p.R86S | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.954); catalogued as COSV59192455; called by muse, mutect2, varscan2
- BRCA1 | c.3097G>A p.E1033K | Missense Mutation (SNP) | VAF 84/233 reads (36%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.688); catalogued as rs273899698, COSV100524646, COSV58789807; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BRF1 | c.104A>T p.N35I | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs771740040, COSV59268877; called by muse, mutect2, varscan2
- BRWD1 | c.839C>T p.P280L | Missense Mutation (SNP) | VAF 60/151 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs747383029, COSV100312614, COSV60895736; called by muse, mutect2, varscan2
- BSN | c.8873T>G p.L2958R | Missense Mutation (SNP) | VAF 10/14 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56517845; called by muse, mutect2, varscan2
- BTK | c.1150G>A p.A384T | Missense Mutation (SNP) | VAF 285/630 reads (45%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.616); catalogued as COSV58120010; called by muse, mutect2, varscan2
- BUD13 | c.1471_1472dup p.D491Efs*26 | Frame Shift Ins (INS) | VAF 149/391 reads (38%) | catalogued as rs755085427; called by mutect2, varscan2
- C1orf94 | c.738G>C p.K246N (on ENST00000488417 / NM_001134734.2; = p.K56N on NM_032884.5) | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); catalogued as COSV64913994; called by muse, mutect2, varscan2
- CACNA1H | c.373G>A p.D125N | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.888); catalogued as COSV61990414; called by muse, mutect2, varscan2
- CACNA1H | c.5116G>A p.A1706T | Missense Mutation (SNP) | VAF 29/97 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.934); catalogued as rs761499667, COSV61988129, COSV61999777; called by muse, mutect2, varscan2
- CACNG5 | c.806A>G p.Q269R | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); catalogued as COSV50055758; called by muse, mutect2, varscan2
- CAP2 | c.238A>G p.S80G | Missense Mutation (SNP) | VAF 44/218 reads (20%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs765705086, COSV57732218; called by muse, mutect2, varscan2
- CCDC102B | c.1053+1G>T p.X351_splice | Splice Site (SNP) | VAF 86/212 reads (41%) | catalogued as COSV60141773; called by muse, varscan2
- CCDC88B | c.190C>T p.R64W | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.099); catalogued as COSV57266182; called by muse, mutect2, varscan2
- CCIN | c.400T>G p.L134V | Missense Mutation (SNP) | VAF 12/159 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV100631669; called by muse, mutect2
- CDH1 | c.1817A>T p.N606I | Missense Mutation (SNP) | VAF 27/135 reads (20%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.497); catalogued as COSV55732707, COSV99028549; called by muse, mutect2, varscan2
- CDK17 | c.253A>G p.M85V | Missense Mutation (SNP) | VAF 75/183 reads (41%) | SIFT tolerated, low confidence (0.65); PolyPhen benign (0); catalogued as COSV54129056; called by muse, mutect2, varscan2
- CDK5RAP2 | c.3760T>C p.S1254P | Missense Mutation (SNP) | VAF 94/212 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV62574298; called by muse, mutect2, varscan2
- CDKL4 | c.805A>G p.M269V | Missense Mutation (SNP) | VAF 99/303 reads (33%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.688); catalogued as COSV66509590; called by muse, mutect2, varscan2
- CDX2 | c.916dup p.V306Gfs*31 | Frame Shift Ins (INS) | VAF 47/116 reads (41%) | catalogued as rs773511514; called by mutect2, varscan2
- CFAP46 | c.368C>T p.P123L | Missense Mutation (SNP) | VAF 159/346 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.856); catalogued as rs147692882; called by muse, mutect2, varscan2
- CHD9 | c.7456C>T p.P2486S (on ENST00000398510 / NM_001382353.1; = p.P2470S on NM_025134.7) | Missense Mutation (SNP) | VAF 14/217 reads (6%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.991); catalogued as COSV54609205; called by muse, mutect2
- CIB1 | c.461A>G p.D154G | Missense Mutation (SNP) | VAF 55/123 reads (45%) | SIFT tolerated (0.1); PolyPhen benign (0.066); catalogued as COSV60173538; called by muse, mutect2, varscan2
- CKAP2L | c.2171A>G p.K724R | Missense Mutation (SNP) | VAF 47/124 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.023); catalogued as COSV56696498; called by muse, mutect2, varscan2
- CLASP1 | c.1979G>A p.R660Q | Missense Mutation (SNP) | VAF 53/129 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.068); catalogued as rs750384484, COSV55323851, COSV55337423; called by muse, mutect2, varscan2
- CLPX | c.244T>C p.S82P | Missense Mutation (SNP) | VAF 148/366 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.044); catalogued as COSV55644527; called by muse, mutect2, varscan2
- CNTN5 | c.401G>A p.R134K | Missense Mutation (SNP) | VAF 258/589 reads (44%) | SIFT tolerated (0.05); PolyPhen benign (0.001); catalogued as COSV54310365; called by muse, mutect2, varscan2
- COL1A1 | c.2258C>T p.A753V | Missense Mutation (SNP) | VAF 65/140 reads (46%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.711); catalogued as COSV56804900; called by muse, mutect2, varscan2
- COPS6 | c.747G>T p.E249D | Missense Mutation (SNP) | VAF 100/274 reads (36%) | SIFT tolerated (0.52); PolyPhen benign (0.055); catalogued as COSV57996409; called by muse, mutect2, varscan2
- CPNE6 | c.423G>A p.T141= | Splice Region (SNP) | VAF 41/110 reads (37%) | catalogued as rs1177493473, COSV53744096; called by muse, mutect2, varscan2
- CRCP | c.68T>C p.L23P | Missense Mutation (SNP) | VAF 101/227 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58535585; called by muse, mutect2, varscan2
- CRTAC1 | c.401A>G p.N134S | Missense Mutation (SNP) | VAF 32/92 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs773929079, COSV54001627; called by muse, mutect2, varscan2
- CSGALNACT1 | c.852-2A>G p.X284_splice | Splice Site (SNP) | VAF 105/288 reads (36%) | catalogued as COSV59977555; called by muse, mutect2, varscan2
- CSPG4 | c.560A>G p.D187G | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT tolerated (0.26); PolyPhen benign (0.011); catalogued as COSV57894972; called by muse, mutect2, varscan2
- CUL4A | c.1811A>C p.E604A (on ENST00000375440 / NM_001008895.4; = p.E504A on NM_003589.3) | Missense Mutation (SNP) | VAF 62/156 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.062); catalogued as COSV58372894; called by muse, mutect2, varscan2
- CXCR5 | c.578G>A p.G193D | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as COSV52684354; called by muse, mutect2, varscan2
- CXXC1 | c.1877T>C p.M626T | Missense Mutation (SNP) | VAF 55/111 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.785); catalogued as COSV53274546; called by muse, mutect2, varscan2
- CXXC5 | c.850C>T p.R284* | Nonsense Mutation (SNP) | VAF 11/30 reads (37%) | catalogued as COSV56793875; called by muse, mutect2, varscan2
- DACT1 | c.2245T>C p.Y749H | Missense Mutation (SNP) | VAF 60/137 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60020719; called by muse, mutect2, varscan2
- DAGLB | c.1100A>C p.E367A | Missense Mutation (SNP) | VAF 55/144 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.285); catalogued as COSV51703944; called by muse, mutect2, varscan2
- DCAF12L2 | c.938C>A p.T313N | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.522); catalogued as COSV63581669; called by muse, mutect2, varscan2
- DCN | c.300C>A p.D100E | Missense Mutation (SNP) | VAF 158/424 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV50007114; called by muse, mutect2, varscan2
- DCX | c.1022G>A p.G341D (on ENST00000636035 / NM_001195553.2; = p.G336D on NM_000555.3) | Missense Mutation (SNP) | VAF 168/363 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.638); catalogued as COSV57569449; called by muse, mutect2, varscan2
- DENND2A | c.1700A>T p.Y567F | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT deleterious (0.05); PolyPhen benign (0.179); catalogued as COSV52051437; called by muse, mutect2, varscan2
- DENND2D | c.781G>A p.A261T | Missense Mutation (SNP) | VAF 36/80 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV62959143; called by muse, mutect2, varscan2
- DENND4A | c.1997A>C p.D666A | Missense Mutation (SNP) | VAF 184/420 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV71265785; called by muse, mutect2, varscan2
- DGCR8 | c.1385C>T p.A462V | Missense Mutation (SNP) | VAF 91/231 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as COSV61226657; called by muse, mutect2, varscan2
- DIS3L | c.1234C>T p.R412C (on ENST00000319212 / NM_001143688.3; = p.R329C on NM_133375.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 240/581 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.053); catalogued as rs773245840, COSV59912284; called by muse, mutect2, varscan2
- DISP1 | c.3760C>G p.P1254A | Missense Mutation (SNP) | VAF 51/123 reads (41%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.006); catalogued as COSV52658847; called by muse, mutect2, varscan2
- DLX2 | c.200A>G p.Y67C | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52232113; called by muse, mutect2, varscan2
- DMD | c.4351T>A p.L1451I | Missense Mutation (SNP) | VAF 94/227 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.323); catalogued as COSV100819135; called by muse, mutect2, varscan2
- DNAH3 | c.1240T>A p.S414T | Missense Mutation (SNP) | VAF 68/153 reads (44%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV54521484; called by muse, mutect2, varscan2
- DNAJA3 | c.475T>C p.S159P | Missense Mutation (SNP) | VAF 53/171 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.548); catalogued as COSV52161970; called by muse, mutect2, varscan2
- DNM2 | c.1091G>A p.R364H | Missense Mutation (SNP) | VAF 24/148 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.12); catalogued as COSV58957489, COSV58961647; called by muse, mutect2, varscan2
- DOCK11 | c.4430A>G p.N1477S | Missense Mutation (SNP) | VAF 123/315 reads (39%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as COSV52238999; called by muse, mutect2, varscan2
- DPF2 | c.959A>G p.Y320C | Missense Mutation (SNP) | VAF 106/269 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52889284; called by muse, mutect2, varscan2
- DPP3 | c.893G>A p.R298H | Missense Mutation (SNP) | VAF 34/87 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.851); catalogued as rs201367893, COSV64756786; called by muse, mutect2, varscan2
- DST | c.20152A>C p.I6718L (on ENST00000361203 / NM_001374722.1; = p.I4415L on NM_015548.5) | Missense Mutation (SNP) | VAF 76/196 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.395); catalogued as COSV55014364; called by muse, varscan2
- DZIP3 | c.1778T>C p.I593T | Missense Mutation (SNP) | VAF 78/201 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.031); catalogued as COSV64312083; called by muse, mutect2, varscan2
- EDC4 | c.726del p.E243Rfs*51 | Frame Shift Del (DEL) | VAF 16/77 reads (21%) | catalogued as COSV62766034; called by mutect2, pindel, varscan2
- EFCAB7 | c.1846C>T p.R616* | Nonsense Mutation (SNP) | VAF 63/191 reads (33%) | catalogued as rs1228928975, COSV64314325; called by muse, mutect2, varscan2
- EGR4 | c.1048A>C p.S350R (on ENST00000545030; = p.S247R on NM_001965.4) | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.197); catalogued as rs781551393, COSV71532032; called by muse, mutect2, varscan2
- EMCN | c.244A>G p.T82A | Missense Mutation (SNP) | VAF 111/248 reads (45%) | SIFT tolerated (0.1); PolyPhen benign (0.333); catalogued as rs780809242, COSV56459094; called by muse, mutect2, varscan2
- ERCC6 | c.2045T>G p.L682R | Missense Mutation (SNP) | VAF 53/123 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100875731, COSV63390066; called by muse, mutect2, varscan2
- EXO1 | c.1522dup p.C508Lfs*7 | Frame Shift Ins (INS) | VAF 83/225 reads (37%) | catalogued as rs763386152; called by mutect2, varscan2
- EYA1 | c.1702G>A p.A568T | Missense Mutation (SNP) | VAF 28/75 reads (37%) | SIFT deleterious (0.05); PolyPhen benign (0.052); catalogued as rs773461292, COSV58156687; called by muse, mutect2, varscan2
- EZH2 | c.1045C>T p.R349C (on ENST00000460911 / NM_001203247.2; = p.R354C on NM_004456.5) | Missense Mutation (SNP) | VAF 132/307 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV57453121, COSV57463823; called by muse, mutect2, varscan2
- FAAP100 | c.2234T>C p.V745A | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as COSV59885338; called by muse, mutect2, varscan2
- FADS3 | c.1264A>G p.T422A | Missense Mutation (SNP) | VAF 25/52 reads (48%) | SIFT tolerated (0.41); PolyPhen benign (0.025); catalogued as COSV53878539; called by muse, mutect2, varscan2
- FAM120A | c.1650dup p.V551Rfs*4 | Frame Shift Ins (INS) | VAF 26/91 reads (29%) | catalogued as rs1302998579; called by mutect2, pindel, varscan2
- FAM172A | c.106+2T>C p.X36_splice | Splice Site (SNP) | VAF 146/428 reads (34%) | catalogued as COSV67937482; called by muse, mutect2, varscan2
- FAT2 | c.8830T>C p.C2944R | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99941282; called by muse, mutect2
- FAT3 | c.8459A>G p.D2820G | Missense Mutation (SNP) | VAF 49/118 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.093); catalogued as COSV53109812; called by muse, mutect2, varscan2
- FAT4 | c.12139A>G p.T4047A | Missense Mutation (SNP) | VAF 8/182 reads (4%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.979); catalogued as rs998370870, COSV100626822; called by muse, mutect2
- FBXO3 | c.121C>T p.R41* | Nonsense Mutation (SNP) | VAF 70/188 reads (37%) | catalogued as rs758687860, COSV55766153; called by muse, mutect2, varscan2
- FCHO1 | c.2098C>T p.P700S | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.999); catalogued as COSV53182606; called by muse, varscan2
- FECH | c.224A>G p.N75S | Missense Mutation (SNP) | VAF 134/322 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50490936; called by muse, mutect2, varscan2
- FGG | c.83T>C p.V28A | Missense Mutation (SNP) | VAF 108/270 reads (40%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.012); catalogued as COSV60195331; called by muse, mutect2, varscan2
- FLNA | c.5874G>A p.M1958I (on ENST00000369850 / NM_001110556.2; = p.M1950I on NM_001456.3) | Missense Mutation (SNP) | VAF 35/63 reads (56%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV100774330, COSV61042951; called by muse, mutect2, varscan2
- FLNA | c.5198A>G p.N1733S (on ENST00000369850 / NM_001110556.2; = p.N1725S on NM_001456.3) | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.297); catalogued as COSV61042967; called by muse, mutect2, varscan2
- FMN1 | c.3154G>T p.D1052Y (on ENST00000616417 / NM_001277313.2; = p.D829Y on NM_001103184.4) | Missense Mutation (SNP) | VAF 81/173 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57922958; called by muse, mutect2, varscan2
- FOXP1 | c.1830G>T p.M610I | Missense Mutation (SNP) | VAF 16/433 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0.085); catalogued as COSV59543245; called by muse, mutect2
- FREM1 | c.620dup p.E209Rfs*30 | Frame Shift Ins (INS) | VAF 23/57 reads (40%) | catalogued as rs992970260; called by mutect2, pindel, varscan2
- FUT10 | c.695G>A p.R232H | Missense Mutation (SNP) | VAF 104/212 reads (49%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.759); catalogued as rs367637252, COSV59451669; called by muse, mutect2, varscan2
- FZD3 | c.1630A>G p.I544V | Missense Mutation (SNP) | VAF 76/173 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1563406026, COSV53535487; called by muse, mutect2, varscan2
- FZD5 | c.508C>T p.P170S | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as COSV54943588; called by muse, mutect2, varscan2
- GARNL3 | c.2380G>A p.A794T | Missense Mutation (SNP) | VAF 43/103 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.095); catalogued as COSV59226305; called by muse, mutect2, varscan2
- GATA5 | c.524-2A>G p.X175_splice | Splice Site (SNP) | VAF 15/34 reads (44%) | catalogued as COSV53345968; called by muse, mutect2, varscan2
- GDF2 | c.901G>A p.E301K | Missense Mutation (SNP) | VAF 43/113 reads (38%) | SIFT tolerated (0.46); PolyPhen benign (0.043); catalogued as rs41314469; ClinVar: likely benign; called by muse, mutect2, varscan2
- GDF7 | c.1253C>T p.A418V | Missense Mutation (SNP) | VAF 38/71 reads (54%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.874); catalogued as rs1257142842; called by muse, mutect2, varscan2
- GLYR1 | c.1140dup p.R381Afs*15 | Frame Shift Ins (INS) | VAF 42/59 reads (71%) | catalogued as rs749150409; called by mutect2, varscan2
- GNAI2 | c.511A>G p.T171A | Missense Mutation (SNP) | VAF 40/108 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.244); catalogued as COSV56493990; called by muse, mutect2, varscan2
- GPR179 | c.1727G>A p.R576H (on ENST00000621958; = p.R575H on NM_001004334.4) | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs376028313; called by muse, mutect2
- GPR6 | c.226G>T p.D76Y | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.898); catalogued as COSV51571899; called by muse, mutect2, varscan2
- GRIK1 | c.1040A>G p.Q347R | Missense Mutation (SNP) | VAF 43/113 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV58718143; called by muse, mutect2, varscan2
- GRM5 | c.604A>G p.M202V | Missense Mutation (SNP) | VAF 64/152 reads (42%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.938); catalogued as COSV59605082; called by muse, mutect2, varscan2
- GSE1 | c.366dup p.V123Rfs*17 | Frame Shift Ins (INS) | VAF 23/44 reads (52%) | catalogued as rs754199513; called by mutect2, varscan2
- GSK3A | c.1132G>A p.A378T | Missense Mutation (SNP) | VAF 48/121 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.018); catalogued as rs758365091, COSV55899281; called by muse, mutect2, varscan2
- GTF3C1 | c.3314A>G p.D1105G | Missense Mutation (SNP) | VAF 87/207 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as COSV62241245; called by muse, mutect2, varscan2
- HCFC1R1 | c.23A>G p.Q8R | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV50187550; called by muse, mutect2, varscan2
- HECW1 | c.1731C>G p.S577R | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.088); catalogued as COSV67826695, COSV67829472; called by muse, mutect2, varscan2
- HMGCR | c.379T>C p.F127L | Missense Mutation (SNP) | VAF 241/582 reads (41%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.999); catalogued as COSV55315639; called by muse, mutect2, varscan2
- HUNK | c.1333del p.R445Efs*28 | Frame Shift Del (DEL) | VAF 69/191 reads (36%) | catalogued as rs1568944534, COSV54233567; called by mutect2, pindel, varscan2
- HUWE1 | c.11768T>C p.L3923S | Missense Mutation (SNP) | VAF 83/230 reads (36%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.767); catalogued as COSV53345415; called by muse, mutect2, varscan2
- IFT140 | c.4298G>A p.R1433H | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs138420849, COSV99248205; ClinVar: likely benign; called by muse, mutect2, varscan2
- IGBP1 | c.742A>G p.N248D | Missense Mutation (SNP) | VAF 81/208 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV60556194; called by muse, mutect2, varscan2
- IGSF22 | c.91A>T p.T31S | Missense Mutation (SNP) | VAF 12/258 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.837); catalogued as COSV100078910; called by muse, mutect2
- INHBE | c.647A>G p.Q216R | Missense Mutation (SNP) | VAF 35/83 reads (42%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV56988091; called by muse, mutect2, varscan2
- INSR | c.3275T>C p.V1092A | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57162667; called by muse, mutect2, varscan2
- IQSEC1 | c.1529G>A p.R510H | Missense Mutation (SNP) | VAF 69/161 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs780572634, COSV56223871; called by muse, mutect2, varscan2
- IQSEC2 | c.848G>C p.G283A (on ENST00000642864 / NM_001111125.3; = p.G78A on NM_015075.2) | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.015); catalogued as rs1241595562, COSV64726734; ClinVar: uncertain significance; called by mutect2, varscan2
- IRAK1 | c.1973C>T p.P658L | Missense Mutation (SNP) | VAF 54/107 reads (50%) | SIFT tolerated (0.23); PolyPhen benign (0.08); catalogued as rs377582537, COSV64110599; called by muse, mutect2, varscan2
- ITIH6 | c.3896A>G p.H1299R | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT tolerated (0.05); PolyPhen benign (0.26); catalogued as COSV54489120; called by muse, mutect2, varscan2
- KAT6B | c.5117A>G p.Y1706C | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.971); catalogued as COSV54746735; called by muse, mutect2, varscan2
- KCNH4 | c.642dup p.S215Vfs*39 | Frame Shift Ins (INS) | VAF 28/78 reads (36%) | catalogued as rs753954093; called by mutect2, varscan2
- KCNK13 | c.670T>C p.Y224H | Missense Mutation (SNP) | VAF 91/208 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56413125; called by muse, mutect2, varscan2
- KCNK15 | c.709G>A p.A237T | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV65719709; called by muse, mutect2
- KDR | c.3652G>C p.A1218P | Missense Mutation (SNP) | VAF 111/254 reads (44%) | SIFT tolerated (0.35); PolyPhen benign (0.012); catalogued as COSV55765025; called by muse, mutect2, varscan2
- KIAA1217 | c.1481G>C p.G494A | Missense Mutation (SNP) | VAF 39/55 reads (71%) | SIFT tolerated (0.8); PolyPhen probably damaging (0.987); catalogued as COSV56812354, COSV56812844; called by muse, mutect2, varscan2
- KIAA1755 | c.3029C>A p.P1010H | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.753); catalogued as COSV54076487; called by muse, mutect2, varscan2
- KIF1B | c.4451G>T p.R1484L (on ENST00000377086 / NM_001365952.1; = p.R1438L on NM_015074.3) | Missense Mutation (SNP) | VAF 42/96 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV55808696, COSV55815884; called by muse, mutect2, varscan2
- KLF12 | c.1047T>G p.C349W | Missense Mutation (SNP) | VAF 46/126 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV66573503; called by muse, mutect2, varscan2
- KLHL32 | c.295T>G p.F99V | Missense Mutation (SNP) | VAF 12/323 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100987033; called by muse, mutect2
- KMT2B | c.611A>G p.Q204R | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV52890556; called by muse, mutect2, varscan2
- KRT1 | c.413G>A p.G138E | Missense Mutation (SNP) | VAF 288/768 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.133); catalogued as COSV52866791; called by muse, mutect2, varscan2
- KRTAP9-8 | c.328_329insTTGT p.T110Ifs*28 | Frame Shift Ins (INS) | VAF 73/104 reads (70%) | catalogued as COSV54199902; called by pindel, varscan2
- LAMA5 | c.10640T>C p.L3547P | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53360102; called by muse, mutect2, varscan2
- LCT | c.340C>T p.R114W | Missense Mutation (SNP) | VAF 96/246 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV51466311; called by muse, mutect2, varscan2
- LIG3 | c.2465T>C p.L822P | Missense Mutation (SNP) | VAF 72/180 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52007644; called by muse, mutect2, varscan2
- LMBRD1 | c.175A>T p.I59F | Missense Mutation (SNP) | VAF 164/338 reads (49%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as COSV65297203; called by muse, mutect2, varscan2
- LONP1 | c.1619T>G p.L540R | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62261658; called by muse, mutect2, varscan2
- LPCAT1 | c.308T>C p.M103T | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT tolerated (0.61); PolyPhen benign (0.01); catalogued as COSV52037528; called by muse, mutect2, varscan2
- LPP | c.1661G>A p.R554H | Missense Mutation (SNP) | VAF 120/281 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1467805710, COSV57091083; called by muse, mutect2, varscan2
- LRBA | c.4489A>G p.I1497V | Missense Mutation (SNP) | VAF 40/92 reads (43%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs1411258646, COSV63955394; called by muse, mutect2, varscan2
- LRIF1 | c.416G>C p.G139A | Missense Mutation (SNP) | VAF 83/177 reads (47%) | SIFT tolerated (0.95); PolyPhen benign (0.078); catalogued as COSV63897333; called by muse, mutect2, varscan2
- LRIG3 | c.2841T>C p.G947= | Splice Region (SNP) | VAF 124/277 reads (45%) | catalogued as COSV57863696; called by muse, mutect2, varscan2
- LRP1 | c.4863C>G p.D1621E | Missense Mutation (SNP) | VAF 56/141 reads (40%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.978); catalogued as COSV54511128; called by muse, mutect2, varscan2
- LRRC4 | c.1183G>A p.A395T | Missense Mutation (SNP) | VAF 61/123 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.458); catalogued as rs369606572, COSV50813485; called by muse, mutect2, varscan2
- LRRC4 | c.308T>C p.V103A | Missense Mutation (SNP) | VAF 140/311 reads (45%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.751); catalogued as COSV50813974; called by mutect2, varscan2
- LRRN3 | c.1065G>C p.E355D | Missense Mutation (SNP) | VAF 62/140 reads (44%) | SIFT tolerated (0.17); PolyPhen benign (0.028); catalogued as COSV57818591, COSV57819652; called by muse, mutect2, varscan2
- LUC7L | c.932G>A p.R311Q | Missense Mutation (SNP) | VAF 6/71 reads (8%) | SIFT tolerated, low confidence (0.12); PolyPhen probably damaging (0.921); catalogued as COSV99550907; called by muse, mutect2
- MACF1 | c.930+2T>C p.X310_splice | Splice Site (SNP) | VAF 153/364 reads (42%) | catalogued as COSV58373360; called by muse, mutect2, varscan2
- MACF1 | c.18991-2A>G p.X6331_splice (on ENST00000372915; = p.X4376_splice on NM_012090.5) | Splice Site (SNP) | VAF 88/213 reads (41%) | catalogued as COSV57120956; called by muse, mutect2, varscan2
- MAN2B1 | c.1527C>T p.R509= | Splice Region (SNP) | VAF 12/32 reads (38%) | catalogued as rs1486751691, COSV99667246; called by muse, mutect2, varscan2
- MAPRE3 | c.543dup p.C182Lfs*16 | Frame Shift Ins (INS) | VAF 16/52 reads (31%) | catalogued as rs777328830; called by mutect2, varscan2
- MARF1 | c.3122T>C p.V1041A | Missense Mutation (SNP) | VAF 80/192 reads (42%) | SIFT tolerated (0.72); PolyPhen benign (0.003); catalogued as rs1397729948, COSV60023496; called by muse, mutect2, varscan2
- MASTL | c.116A>G p.K39R | Missense Mutation (SNP) | VAF 51/72 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV58759448; called by muse, mutect2, varscan2
- MATK | c.218A>G p.D73G (on ENST00000310132 / NM_139355.3; = p.D74G on NM_002378.4) | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as COSV59554518; called by muse, varscan2
- MBTPS1 | c.2964G>A p.G988= | Splice Region (SNP) | VAF 24/43 reads (56%) | catalogued as COSV58570750; called by muse, mutect2, varscan2
- MCHR2 | c.623del p.F208Sfs*5 | Frame Shift Del (DEL) | VAF 210/258 reads (81%) | catalogued as rs759525627, COSV55999002; called by mutect2, varscan2
- MECOM | c.2672A>G p.E891G (on ENST00000468789 / NM_001105078.4; = p.E1079G on NM_004991.4) | Missense Mutation (SNP) | VAF 138/344 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.115); catalogued as COSV52964375; called by muse, mutect2, varscan2
- MED13L | c.6351T>A p.C2117* | Nonsense Mutation (SNP) | VAF 92/221 reads (42%) | catalogued as COSV56120005; called by muse, mutect2, varscan2
- MED23 | c.133A>G p.R45G | Missense Mutation (SNP) | VAF 116/254 reads (46%) | SIFT tolerated (0.38); PolyPhen benign (0.011); catalogued as COSV63432462; called by muse, mutect2, varscan2
- MMS19 | c.1165G>A p.V389I | Missense Mutation (SNP) | VAF 32/93 reads (34%) | SIFT tolerated (0.97); PolyPhen benign (0); catalogued as COSV59135109; called by muse, mutect2, varscan2
- MOCS2 | c.407T>C p.I136T | Missense Mutation (SNP) | VAF 59/122 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.783); catalogued as COSV63740879; called by muse, mutect2, varscan2
- MORC1 | c.2641dup p.I881Nfs*11 | Frame Shift Ins (INS) | VAF 136/382 reads (36%) | catalogued as rs757379917; called by mutect2, varscan2
- MRTFA | c.1078G>A p.A360T | Missense Mutation (SNP) | VAF 112/251 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); catalogued as rs757570875, COSV62933263, COSV62933387, COSV62933980; called by muse, mutect2, varscan2
- MS4A8 | c.134T>C p.L45P | Missense Mutation (SNP) | VAF 92/212 reads (43%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.564); catalogued as rs1225836566, COSV55754265; called by muse, mutect2, varscan2
- MTMR9 | c.487A>G p.T163A | Missense Mutation (SNP) | VAF 14/408 reads (3%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV99643831; called by muse, mutect2
- MUC5B | c.262T>G p.F88V | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV71592048; called by muse, mutect2, varscan2
- MYO1D | c.2932A>G p.T978A | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT tolerated (0.77); PolyPhen benign (0.05); catalogued as rs1260080596, COSV57830900; called by muse, mutect2, varscan2
- MYO7B | c.4061G>A p.S1354N | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT tolerated (0.27); PolyPhen benign (0.034); catalogued as COSV67347693; called by muse, mutect2, varscan2
- NAA15 | c.1841del p.N614Mfs*22 | Frame Shift Del (DEL) | VAF 58/266 reads (22%) | catalogued as rs1283385686, COSV56718069; called by mutect2, varscan2
- NAV3 | c.414G>A p.M138I | Missense Mutation (SNP) | VAF 119/254 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.925); catalogued as rs1429604941, COSV57079637; called by muse, mutect2, varscan2
- NAV3 | c.6715+2T>C p.X2239_splice (on ENST00000397909 / NM_001024383.2; = p.X2217_splice on NM_014903.6) | Splice Site (SNP) | VAF 88/167 reads (53%) | catalogued as COSV57079648; called by muse, mutect2, varscan2
- NCAPG | c.1814T>C p.V605A | Missense Mutation (SNP) | VAF 192/466 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1379631618, COSV52270010; called by muse, mutect2, varscan2
- NCDN | c.1346C>T p.P449L | Missense Mutation (SNP) | VAF 30/72 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.045); catalogued as COSV61935728; called by muse, mutect2, varscan2
- NCKAP1 | c.1957G>A p.G653R | Missense Mutation (SNP) | VAF 211/495 reads (43%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.779); catalogued as COSV62941164; called by muse, mutect2, varscan2
- NCOA4 | c.788A>G p.K263R | Missense Mutation (SNP) | VAF 22/86 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.025); catalogued as rs782412140; called by muse, mutect2, varscan2
- NEB | c.19802T>C p.V6601A | Missense Mutation (SNP) | VAF 360/864 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.187); catalogued as COSV51397342; called by muse, mutect2, varscan2
- NF1 | c.2515A>G p.N839D | Missense Mutation (SNP) | VAF 37/108 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs755956826, COSV100648036, COSV62203277; called by muse, mutect2, varscan2
- NFASC | c.3122T>C p.V1041A | Missense Mutation (SNP) | VAF 31/193 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.088); catalogued as rs1185235923, COSV58365439; called by muse, mutect2, varscan2
- NGEF | c.199C>T p.R67C | Missense Mutation (SNP) | VAF 307/758 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.635); catalogued as rs143190519; called by muse, mutect2, varscan2
- NHP2 | c.242T>C p.L81S | Missense Mutation (SNP) | VAF 72/177 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as COSV51070967; called by muse, mutect2, varscan2
- NID2 | c.3803T>C p.L1268P | Missense Mutation (SNP) | VAF 156/399 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53496352; called by muse, mutect2, varscan2
- NKIRAS2 | c.157dup p.V53Gfs*9 | Frame Shift Ins (INS) | VAF 39/114 reads (34%) | catalogued as rs781916716; called by mutect2, pindel, varscan2
- NLE1 | c.481A>G p.S161G | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.315); catalogued as COSV62604195; called by muse, mutect2, varscan2
- NOBOX | c.487del p.R163Afs*11 | Frame Shift Del (DEL) | VAF 32/77 reads (42%) | catalogued as rs754069719; called by mutect2, pindel, varscan2
- NOD1 | c.2381dup p.N794Kfs*6 | Frame Shift Ins (INS) | VAF 118/400 reads (30%) | catalogued as rs757233885; called by mutect2, pindel, varscan2
- NOTCH2 | c.2141A>G p.H714R | Missense Mutation (SNP) | VAF 75/203 reads (37%) | SIFT tolerated (0.13); PolyPhen benign (0.038); catalogued as COSV56691351; called by muse, mutect2, varscan2
- NOTCH3 | c.5317G>A p.G1773S | Missense Mutation (SNP) | VAF 29/112 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.844); catalogued as COSV54634723; called by muse, mutect2, varscan2
- NOTCH3 | c.605C>T p.A202V | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.719); catalogued as rs767539048, COSV54634737; called by muse, mutect2, varscan2
- NR2C1 | c.326T>G p.V109G | Missense Mutation (SNP) | VAF 108/264 reads (41%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs1193721045, COSV58009868; called by muse, varscan2
- NT5C1B | c.40G>A p.G14R | Missense Mutation (SNP) | VAF 178/423 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.898); catalogued as rs150854562; called by muse, mutect2, varscan2
- NUP93 | c.2036T>G p.I679R | Missense Mutation (SNP) | VAF 107/434 reads (25%) | SIFT tolerated (0.35); PolyPhen benign (0.033); catalogued as COSV57430879; called by muse, mutect2, varscan2
- OAS3 | c.180A>G p.G60= | Splice Region (SNP) | VAF 31/92 reads (34%) | catalogued as COSV57445702; called by muse, mutect2, varscan2
- OBSCN | c.6889C>T p.R2297W | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs772712181, COSV52773842; called by muse, mutect2, varscan2
- OR10G4 | c.412A>G p.S138G | Missense Mutation (SNP) | VAF 117/281 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.207); catalogued as rs1433256461, COSV57977593; called by muse, mutect2, varscan2
- OR2T6 | c.454G>T p.G152W | Missense Mutation (SNP) | VAF 20/258 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63217209; called by muse, mutect2
- OR4A15 | c.419T>C p.V140A | Missense Mutation (SNP) | VAF 143/312 reads (46%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.034); catalogued as COSV59035262; called by muse, mutect2, varscan2
- OR51A7 | c.365G>A p.R122H | Missense Mutation (SNP) | VAF 76/184 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.103); catalogued as rs770538147, COSV63788344; called by muse, mutect2, varscan2
- OR6C75 | c.94A>G p.T32A | Missense Mutation (SNP) | VAF 54/141 reads (38%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.044); catalogued as COSV58552216; called by muse, mutect2, varscan2
- P2RY12 | c.485T>C p.L162P | Missense Mutation (SNP) | VAF 103/249 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56378818; called by muse, mutect2, varscan2
- PANK1 | c.1199dup p.P401Afs*5 (on ENST00000307534 / NM_148977.2; = p.P176Afs*5 on NM_138316.4) | Frame Shift Ins (INS) | VAF 53/364 reads (15%) | catalogued as rs1564621823; called by mutect2, varscan2
- PDZD2 | c.3493A>G p.K1165E | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.084); catalogued as rs1416001390; called by muse, mutect2
- PEBP4 | c.406T>C p.Y136H | Missense Mutation (SNP) | VAF 67/160 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56466766; called by muse, mutect2, varscan2
- PHEX | c.1465A>G p.N489D | Missense Mutation (SNP) | VAF 175/407 reads (43%) | SIFT tolerated (0.78); PolyPhen benign (0.025); catalogued as COSV65075552; called by muse, mutect2, varscan2
- PHF2 | c.1475dup p.T493Dfs*21 | Frame Shift Ins (INS) | VAF 15/36 reads (42%) | catalogued as rs769717544; called by mutect2, varscan2
- PIK3C2G | c.3704A>G p.Q1235R (on ENST00000676171; = p.Q1194R on NM_004570.5) | Missense Mutation (SNP) | VAF 134/312 reads (43%) | SIFT tolerated (0.91); PolyPhen benign (0.01); catalogued as COSV56809219; called by muse, mutect2, varscan2
- PKP4 | c.394T>G p.S132A | Missense Mutation (SNP) | VAF 85/188 reads (45%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.559); catalogued as COSV67677094; called by muse, mutect2, varscan2
- PLAC8 | c.109T>A p.C37S | Missense Mutation (SNP) | VAF 38/71 reads (54%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.529); catalogued as COSV61047395; called by muse, mutect2, varscan2
- PLBD1 | c.641dup p.N214Kfs*8 | Frame Shift Ins (INS) | VAF 94/287 reads (33%) | catalogued as rs765177987; called by mutect2, pindel, varscan2
- PLCB3 | c.781G>A p.E261K | Missense Mutation (SNP) | VAF 28/57 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1181657108, COSV54188495; called by muse, mutect2, varscan2
- PLCE1 | c.2027A>G p.D676G | Missense Mutation (SNP) | VAF 72/264 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV53350457; called by muse, mutect2, varscan2
- PLCG2 | c.548T>C p.L183P | Missense Mutation (SNP) | VAF 36/234 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV63869540; called by muse, mutect2, varscan2
- PLEK2 | c.476T>C p.F159S | Missense Mutation (SNP) | VAF 23/394 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99371511; called by muse, mutect2
- PLXNA3 | c.49dup p.A17Gfs*39 | Frame Shift Ins (INS) | VAF 8/14 reads (57%) | catalogued as rs782247826; called by mutect2, varscan2
- PMS2 | c.2105C>A p.A702D | Missense Mutation (SNP) | VAF 47/142 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV56219399, COSV56221623; called by muse, mutect2, varscan2
- PNISR | c.758A>G p.K253R | Missense Mutation (SNP) | VAF 141/303 reads (47%) | SIFT tolerated (0.68); PolyPhen benign (0.003); catalogued as COSV65079476; called by muse, mutect2, varscan2
- PNMA3 | c.929A>G p.K310R | Missense Mutation (SNP) | VAF 61/159 reads (38%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as COSV64722332; called by muse, mutect2, varscan2
- PNMA3 | c.1105C>A p.P369T | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.466); catalogued as COSV64722340; called by muse, mutect2, varscan2
- POLH | c.1030T>A p.L344I | Missense Mutation (SNP) | VAF 123/289 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64779541; called by muse, mutect2, varscan2
- POLM | c.1031C>T p.A344V | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs1396168979, COSV54242546; called by muse, mutect2, varscan2
- PON3 | c.1013G>A p.G338E | Missense Mutation (SNP) | VAF 48/132 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.054); catalogued as COSV55699296, COSV55700493; called by muse, mutect2, varscan2
- PPFIA1 | c.2038T>C p.S680P | Missense Mutation (SNP) | VAF 100/254 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.012); catalogued as COSV54134541; called by muse, mutect2, varscan2
- PPFIA2 | c.3082T>A p.W1028R | Missense Mutation (SNP) | VAF 23/212 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61032259; called by muse, mutect2, varscan2
- PPIP5K2 | c.2995A>G p.T999A | Missense Mutation (SNP) | VAF 84/201 reads (42%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.05); catalogued as COSV58605510; called by muse, mutect2, varscan2
- PPP1R10 | c.2815dup p.L939Pfs*62 | Frame Shift Ins (INS) | VAF 34/107 reads (32%) | catalogued as rs750124216; called by mutect2, varscan2
- PPP2R1A | c.121G>A p.A41T | Missense Mutation (SNP) | VAF 61/145 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.049); catalogued as COSV59044392, COSV99069489; called by muse, mutect2, varscan2
- PPP2R2A | c.1272G>A p.W424* | Nonsense Mutation (SNP) | VAF 113/236 reads (48%) | catalogued as COSV60096956; called by muse, mutect2, varscan2
- PREB | c.1159+1G>A p.X387_splice | Splice Site (SNP) | VAF 51/100 reads (51%) | catalogued as rs769153201, COSV53206061; called by muse, mutect2, varscan2
- PRKD3 | c.2227T>G p.L743V | Missense Mutation (SNP) | VAF 95/223 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.759); catalogued as COSV52213429; called by muse, mutect2, varscan2
- PRKDC | c.10814dup p.N3605Kfs*3 | Frame Shift Ins (INS) | VAF 91/252 reads (36%) | catalogued as rs1284489077; called by mutect2, varscan2
- PRKDC | c.4054T>C p.S1352P | Missense Mutation (SNP) | VAF 154/351 reads (44%) | SIFT tolerated (0.15); PolyPhen benign (0.352); catalogued as COSV58052271; called by muse, mutect2, varscan2
- PRRC2C | c.2411A>G p.E804G (on ENST00000367742; = p.E802G on NM_015172.4) | Missense Mutation (SNP) | VAF 45/112 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.494); catalogued as COSV58905304; called by muse, mutect2, varscan2
- PSD | c.750dup p.S251Qfs*5 | Frame Shift Ins (INS) | VAF 34/81 reads (42%) | catalogued as rs761494960; called by mutect2, varscan2
- PSG4 | c.1123T>C p.S375P | Missense Mutation (SNP) | VAF 268/642 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.072); catalogued as COSV54935703; called by muse, mutect2, varscan2
- PSG4 | c.989-2A>G p.X330_splice | Splice Site (SNP) | VAF 52/249 reads (21%) | catalogued as rs1266123213, COSV54935718; called by muse, mutect2, varscan2
- PTEN | c.800dup p.D268Gfs*30 | Frame Shift Ins (INS) | VAF 91/250 reads (36%) | catalogued as COSV64302388; called by mutect2, pindel, varscan2
- PTPRR | c.89dup p.L30Ffs*4 | Frame Shift Ins (INS) | VAF 153/385 reads (40%) | catalogued as rs1428737881; called by mutect2, pindel, varscan2
- PXDN | c.3248G>A p.R1083Q | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs781648121, COSV53233887; called by muse, mutect2, varscan2
- R3HDM2 | c.2737del p.D913Tfs*41 | Frame Shift Del (DEL) | VAF 42/101 reads (42%) | catalogued as COSV100234622; called by mutect2, pindel, varscan2
- RABGEF1 | c.691C>T p.R231C (on ENST00000439720 / NM_001287061.2; = p.R218C on NM_014504.3 and 29 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 85/183 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as rs772285729, COSV53162315; called by muse, mutect2, varscan2
- RAP1A | c.153T>A p.C51* | Nonsense Mutation (SNP) | VAF 225/487 reads (46%) | catalogued as COSV62727687; called by muse, varscan2
- RBM6 | c.2368T>A p.Y790N | Missense Mutation (SNP) | VAF 196/442 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); catalogued as COSV56482852; called by muse, varscan2
- RCC1L | c.490G>A p.V164I | Missense Mutation (SNP) | VAF 34/83 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs140417187, COSV57319988; called by muse, mutect2, varscan2
- RFC4 | c.1004A>G p.D335G | Missense Mutation (SNP) | VAF 141/279 reads (51%) | SIFT tolerated (0.06); PolyPhen benign (0.12); catalogued as COSV56216966; called by muse, mutect2, varscan2
- RHCE | c.226A>G p.S76G | Missense Mutation (SNP) | VAF 77/194 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0.065); catalogued as rs1331026964, COSV53800448; called by muse, mutect2, varscan2
- RIOX1 | c.1445G>A p.R482Q | Missense Mutation (SNP) | VAF 42/92 reads (46%) | SIFT tolerated (0.46); PolyPhen benign (0.058); catalogued as COSV100407855; called by muse, mutect2, varscan2
- RNF168 | c.271A>G p.R91G | Missense Mutation (SNP) | VAF 84/172 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV58837867; called by muse, mutect2, varscan2
- ROBO2 | c.611T>C p.V204A | Missense Mutation (SNP) | VAF 135/365 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59911270; called by muse, mutect2, varscan2
- ROR2 | c.1770dup p.D591Rfs*126 | Frame Shift Ins (INS) | VAF 13/45 reads (29%) | catalogued as rs749576600; called by mutect2, pindel, varscan2
- ROS1 | c.6957dup p.Q2320Tfs*11 | Frame Shift Ins (INS) | VAF 91/286 reads (32%) | catalogued as rs756068637; called by mutect2, pindel, varscan2
- RPGRIP1 | c.2411A>C p.E804A | Missense Mutation (SNP) | VAF 76/191 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as rs1387094755, COSV52849992; called by muse, mutect2, varscan2
- RPL22 | c.44del p.K15Rfs*5 | Frame Shift Del (DEL) | VAF 62/162 reads (38%) | catalogued as rs759765382, COSV52379423; called by mutect2, varscan2
- RTL9 | c.134A>G p.H45R | Missense Mutation (SNP) | VAF 91/222 reads (41%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.005); catalogued as rs750632292, COSV71825594; called by muse, mutect2, varscan2
- RTTN | c.4811A>T p.K1604I | Missense Mutation (SNP) | VAF 231/558 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.347); catalogued as rs1375044598, COSV55343682, COSV55344852; called by muse, mutect2, varscan2
- RXRG | c.950G>A p.R317H | Missense Mutation (SNP) | VAF 79/206 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs751038970, CM166098, COSV63231678, COSV63232405; called by muse, mutect2, varscan2
- RYR2 | c.892C>T p.R298C | Missense Mutation (SNP) | VAF 84/204 reads (41%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.939); catalogued as rs551099887, COSV63685496; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- RYR3 | c.13712C>T p.A4571V (on ENST00000389232; = p.A4572V on NM_001036.6) | Missense Mutation (SNP) | VAF 105/231 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.696); catalogued as COSV66789174; called by muse, mutect2, varscan2
- SAAL1 | c.995C>T p.A332V | Missense Mutation (SNP) | VAF 76/189 reads (40%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.521); catalogued as rs1401058554, COSV55515672; called by muse, mutect2, varscan2
- SALL4 | c.2983del p.V995Ffs*14 | Frame Shift Del (DEL) | VAF 46/153 reads (30%) | catalogued as rs753320334; called by mutect2, pindel, varscan2
- SAMD9L | c.4630dup p.I1544Nfs*17 | Frame Shift Ins (INS) | VAF 106/283 reads (37%) | catalogued as rs771033613; called by mutect2, pindel, varscan2
- SAR1B | c.226C>A p.L76M | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV68391567; called by muse, mutect2, varscan2
- SCN5A | c.2365G>A p.V789I | Missense Mutation (SNP) | VAF 117/271 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.557); catalogued as rs199473159, CM100673, COSV61115379; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SDK1 | c.562G>A p.A188T | Missense Mutation (SNP) | VAF 53/129 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.918); catalogued as rs774307438, COSV67357841; called by muse, mutect2, varscan2
- SELENOO | c.853G>A p.D285N | Missense Mutation (SNP) | VAF 36/105 reads (34%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.771); catalogued as rs751966456, COSV66599139; called by muse, mutect2, varscan2
- SESN3 | c.1060T>C p.Y354H | Missense Mutation (SNP) | VAF 51/119 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53584930; called by muse, mutect2, varscan2
- SESN3 | c.740C>T p.S247F | Missense Mutation (SNP) | VAF 119/253 reads (47%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.9); catalogued as COSV53584938; called by muse, mutect2, varscan2
- SESTD1 | c.1544A>G p.E515G | Missense Mutation (SNP) | VAF 75/214 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV58931251; called by muse, mutect2, varscan2
- SIK3 | c.572A>G p.D191G (on ENST00000445177 / NM_001366686.2; = p.D197G on NM_025164.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 146/355 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52614333; called by muse, mutect2, varscan2
- SLC12A1 | c.3103C>T p.R1035C | Missense Mutation (SNP) | VAF 57/165 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as rs746030141, COSV66794779; called by muse, mutect2, varscan2
- SLC16A7 | c.1121C>T p.A374V | Missense Mutation (SNP) | VAF 85/194 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747971816, COSV53894989; called by muse, mutect2, varscan2
- SLC17A4 | c.1162G>A p.V388I | Missense Mutation (SNP) | VAF 35/152 reads (23%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.449); catalogued as COSV64956201; called by muse, mutect2, varscan2
- SLC23A2 | c.1762G>T p.V588L | Missense Mutation (SNP) | VAF 152/422 reads (36%) | SIFT tolerated (0.77); PolyPhen benign (0.014); catalogued as COSV57774317; called by muse, mutect2, varscan2
- SLC25A3 | c.192C>G p.F64L | Missense Mutation (SNP) | VAF 175/415 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.411); catalogued as rs762115323, COSV51844289; called by muse, mutect2, varscan2
- SLC27A1 | c.1658T>C p.M553T | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53097357; called by muse, mutect2, varscan2
- SLC35D3 | c.1100C>A p.P367H | Missense Mutation (SNP) | VAF 90/193 reads (47%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); catalogued as COSV59377526, COSV59377780; called by muse, mutect2, varscan2
- SLC38A3 | c.1154T>C p.L385P | Missense Mutation (SNP) | VAF 32/65 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV68844004; called by muse, mutect2, varscan2
- SLC39A5 | c.250C>T p.R84W | Missense Mutation (SNP) | VAF 29/68 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.635); catalogued as rs199681035; called by muse, mutect2, varscan2
- SLC4A8 | c.2774T>C p.F925S | Missense Mutation (SNP) | VAF 132/300 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60652262; called by muse, mutect2, varscan2
- SLC5A4 | c.292A>G p.T98A | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.012); catalogued as rs780834586; called by muse, mutect2, varscan2
- SLC5A9 | c.128T>C p.I43T | Missense Mutation (SNP) | VAF 41/96 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV52583515; called by muse, mutect2, varscan2
- SLC6A4 | c.1135A>G p.I379V | Missense Mutation (SNP) | VAF 87/186 reads (47%) | SIFT tolerated (0.31); PolyPhen benign (0.277); catalogued as COSV55566890; called by muse, mutect2, varscan2
- SLC7A14 | c.1183G>A p.A395T | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.481); catalogued as COSV51582050; called by muse, mutect2, varscan2
- SLCO1B1 | c.950dup p.N317Kfs*14 | Frame Shift Ins (INS) | VAF 83/284 reads (29%) | catalogued as rs1565679506; called by mutect2, pindel, varscan2
- SLIT3 | c.1537G>A p.G513S | Missense Mutation (SNP) | VAF 93/207 reads (45%) | SIFT tolerated (0.15); PolyPhen benign (0.219); catalogued as rs1025472398, COSV60608139; called by muse, mutect2, varscan2
- SMARCAD1 | c.364A>G p.I122V | Missense Mutation (SNP) | VAF 79/150 reads (53%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); catalogued as COSV62774414; called by muse, mutect2, varscan2
- SMG7 | c.557-2A>G p.X186_splice | Splice Site (SNP) | VAF 187/436 reads (43%) | catalogued as COSV61631396; called by muse, mutect2, varscan2
- SMTN | c.163C>T p.R55C | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs762644399, COSV60778096; called by muse, mutect2, varscan2
- SNAP29 | c.665G>T p.G222V | Missense Mutation (SNP) | VAF 133/268 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53142631; called by muse, mutect2, varscan2
- SNRNP200 | c.3253A>G p.T1085A | Missense Mutation (SNP) | VAF 57/148 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.034); catalogued as COSV60489857; called by muse, mutect2, varscan2
- SOGA1 | c.1922C>T p.A641V | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT tolerated (0.35); PolyPhen benign (0.009); catalogued as rs1316942225; called by muse, mutect2
- SOHLH2 | c.1072T>C p.S358P | Missense Mutation (SNP) | VAF 125/268 reads (47%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.96); catalogued as COSV65902094; called by muse, mutect2, varscan2
- SON | c.1708C>T p.P570S | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.288); catalogued as rs760968345, COSV51657614; called by muse, mutect2, varscan2
- SORCS1 | c.3128C>A p.A1043D | Missense Mutation (SNP) | VAF 55/152 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.039); catalogued as COSV53842643; called by muse, mutect2
- SPAG17 | c.282dup p.P95Tfs*5 | Frame Shift Ins (INS) | VAF 130/318 reads (41%) | catalogued as rs771461785; called by mutect2, varscan2
- SPINK9 | c.62A>G p.E21G | Missense Mutation (SNP) | VAF 237/534 reads (44%) | SIFT tolerated (0.25); PolyPhen benign (0.177); catalogued as COSV64957971; called by muse, mutect2, varscan2
- SPOPL | c.898G>A p.E300K | Missense Mutation (SNP) | VAF 158/388 reads (41%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.608); catalogued as COSV54513475, COSV54516563; called by muse, varscan2
- SS18L1 | c.1031G>A p.G344D | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.844); catalogued as COSV59210593; called by muse, mutect2, varscan2
- ST18 | c.2416A>G p.K806E | Missense Mutation (SNP) | VAF 109/271 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs975599641, COSV52494183; called by muse, mutect2, varscan2
- STARD3NL | c.52T>C p.S18P | Missense Mutation (SNP) | VAF 105/221 reads (48%) | SIFT tolerated (0.09); PolyPhen benign (0.021); catalogued as COSV50518382; called by muse, mutect2, varscan2
- STAT2 | c.2087T>G p.I696S | Missense Mutation (SNP) | VAF 78/455 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58475479; called by muse, mutect2, varscan2
- STPG3 | c.226del p.Q76Rfs*11 | Frame Shift Del (DEL) | VAF 34/95 reads (36%) | catalogued as rs773395497; called by mutect2, pindel, varscan2
- STYXL2 | c.2639A>G p.D880G | Missense Mutation (SNP) | VAF 102/228 reads (45%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV54805096; called by muse, mutect2, varscan2
- SUPT16H | c.125A>G p.E42G | Missense Mutation (SNP) | VAF 46/265 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.858); catalogued as COSV53524615; called by muse, mutect2, varscan2
- SYNE3 | c.903A>T p.E301D | Missense Mutation (SNP) | VAF 35/74 reads (47%) | SIFT deleterious (0.05); PolyPhen benign (0.194); catalogued as COSV62079408; called by muse, mutect2, varscan2
- TAF7L | c.62C>T p.S21L | Missense Mutation (SNP) | VAF 12/244 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV100774120; called by muse, mutect2
- TAOK2 | c.1804C>T p.P602S | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.449); catalogued as COSV54235725; called by muse, mutect2, varscan2
- TARBP2 | c.432dup p.M145Hfs*13 (on ENST00000266987 / NM_134323.2; = p.M124Hfs*13 on NM_004178.4) | Frame Shift Ins (INS) | VAF 82/244 reads (34%) | catalogued as rs750181498; called by mutect2, varscan2
- TAS1R2 | c.443T>C p.M148T | Missense Mutation (SNP) | VAF 43/118 reads (36%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV64744985; called by muse, mutect2, varscan2
- TBC1D1 | c.928dup p.I310Nfs*8 | Frame Shift Ins (INS) | VAF 103/284 reads (36%) | catalogued as rs760298745; called by mutect2, varscan2
- TBC1D31 | c.2387A>G p.D796G | Missense Mutation (SNP) | VAF 133/312 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.701); catalogued as COSV54866256; called by muse, mutect2, varscan2
- TCP11 | c.88dup p.Q30Pfs*24 (on ENST00000512012; = p.Q30Pfs*19 on NM_001261817.2) | Frame Shift Ins (INS) | VAF 29/76 reads (38%) | catalogued as rs751330115; called by mutect2, varscan2
- TDRD3 | c.161C>T p.T54I | Missense Mutation (SNP) | VAF 136/258 reads (53%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as COSV52156710; called by muse, mutect2, varscan2
- TDRD5 | c.1236dup p.Q413Tfs*13 | Frame Shift Ins (INS) | VAF 92/245 reads (38%) | catalogued as rs1433075758; called by mutect2, varscan2
- TECRL | c.874A>G p.T292A | Missense Mutation (SNP) | VAF 87/204 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV67087114; called by muse, mutect2, varscan2
- TEKT1 | c.1208A>G p.E403G | Missense Mutation (SNP) | VAF 45/107 reads (42%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as COSV58623150; called by muse, mutect2, varscan2
- TGFB1I1 | c.79C>T p.R27C (on ENST00000394863 / NM_001042454.3; = p.R10C on NM_015927.4) | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.498); catalogued as rs747679972, COSV62357927; called by muse, mutect2, varscan2
- THRAP3 | c.1366del p.V456Sfs*2 | Frame Shift Del (DEL) | VAF 83/213 reads (39%) | catalogued as COSV63567793; called by mutect2, pindel, varscan2
- TLR6 | c.710T>C p.V237A | Missense Mutation (SNP) | VAF 68/173 reads (39%) | SIFT tolerated (0.48); PolyPhen benign (0.019); catalogued as COSV67935239; called by muse, mutect2, varscan2
- TM4SF4 | c.386A>G p.Y129C | Missense Mutation (SNP) | VAF 76/185 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV59515763; called by muse, mutect2, varscan2
- TMCO3 | c.1117T>G p.L373V | Missense Mutation (SNP) | VAF 97/294 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.73); catalogued as COSV64807572; called by muse, mutect2, varscan2
- TMEM120A | c.511T>C p.Y171H | Missense Mutation (SNP) | VAF 39/98 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV100115426; called by muse, mutect2, varscan2
- TMEM131L | c.2956A>T p.K986* | Nonsense Mutation (SNP) | VAF 29/60 reads (48%) | catalogued as COSV53644430; called by muse, mutect2, varscan2
- TMEM132B | c.2419A>G p.N807D | Missense Mutation (SNP) | VAF 76/180 reads (42%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as COSV54753716, COSV54753990; called by muse, mutect2, varscan2
- TMEM63B | c.2248A>G p.T750A | Missense Mutation (SNP) | VAF 54/121 reads (45%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV52478852; called by muse, mutect2, varscan2
- TMPO | c.295del p.T99Lfs*12 | Frame Shift Del (DEL) | VAF 150/332 reads (45%) | catalogued as rs770800449; called by mutect2, varscan2
- TOPBP1 | c.3395A>G p.D1132G | Missense Mutation (SNP) | VAF 31/157 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.28); catalogued as COSV53435886; called by muse, mutect2, varscan2
- TOPBP1 | c.145A>G p.K49E | Missense Mutation (SNP) | VAF 157/373 reads (42%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as COSV53435906; called by muse, mutect2, varscan2
- TP63 | c.1787C>T p.A596V | Missense Mutation (SNP) | VAF 46/128 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.063); catalogued as rs773237715, COSV53205887; called by muse, mutect2, varscan2
- TRIM23 | c.275A>T p.N92I | Missense Mutation (SNP) | VAF 139/317 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51550889; called by muse, mutect2, varscan2
- TRPM6 | c.3163T>C p.F1055L | Missense Mutation (SNP) | VAF 107/247 reads (43%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.646); catalogued as COSV62510070; called by muse, mutect2, varscan2
- TRPM7 | c.1738T>C p.F580L | Missense Mutation (SNP) | VAF 182/398 reads (46%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.523); catalogued as COSV57916378; called by muse, mutect2, varscan2
- TRPM8 | c.2301dup p.E768Rfs*14 | Frame Shift Ins (INS) | VAF 95/336 reads (28%) | catalogued as rs770879940; called by mutect2, varscan2
- TRPS1 | c.3827dup p.N1276Kfs*5 (on ENST00000220888 / NM_001330599.2; = p.N1289Kfs*5 on NM_014112.5 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 94/268 reads (35%) | catalogued as rs1401148397; called by mutect2, varscan2
- TSGA10IP | c.1442T>C p.V481A | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT tolerated (0.48); PolyPhen benign (0.352); catalogued as COSV56711634; called by muse, mutect2, varscan2
- TSNAXIP1 | c.875T>G p.L292R | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54649758, COSV54649777; called by muse, mutect2
- TTC3 | c.1769dup p.N590Kfs*11 | Frame Shift Ins (INS) | VAF 66/168 reads (39%) | catalogued as rs752525442; called by mutect2, varscan2
- TTK | c.2571del p.K857Nfs*36 | Frame Shift Del (DEL) | VAF 35/156 reads (22%) | catalogued as rs768996038, COSV57882295; called by mutect2, pindel, varscan2
- TTLL7 | c.2252G>A p.R751H | Missense Mutation (SNP) | VAF 49/120 reads (41%) | SIFT tolerated (0.17); PolyPhen benign (0.066); catalogued as rs368937222; called by muse, mutect2, varscan2
- TXNDC2 | c.1145T>C p.I382T (on ENST00000306084 / NM_001098529.2; = p.I315T on NM_032243.6) | Missense Mutation (SNP) | VAF 217/533 reads (41%) | SIFT tolerated (0.11); PolyPhen benign (0.247); catalogued as rs773139307, COSV60153430; called by muse, mutect2, varscan2
- UBC | c.544A>G p.I182V | Missense Mutation (SNP) | VAF 167/484 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.036); catalogued as COSV60059453; called by muse, mutect2, varscan2
- UBR2 | c.4182A>G p.A1394= | Splice Region (SNP) | VAF 13/436 reads (3%) | catalogued as COSV100867307; called by muse, mutect2
- UFL1 | c.1484A>G p.E495G | Missense Mutation (SNP) | VAF 23/308 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.113); catalogued as COSV100989992; called by muse, mutect2
- UGGT1 | c.3968G>A p.R1323Q | Missense Mutation (SNP) | VAF 160/366 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.787); catalogued as rs772770875, COSV52135761; called by muse, mutect2, varscan2
- UGT2B28 | c.1218G>T p.M406I | Missense Mutation (SNP) | VAF 203/257 reads (79%) | SIFT deleterious (0.04); PolyPhen benign (0.131); catalogued as COSV59431987; called by muse, mutect2, varscan2
- ULK4 | c.2198T>C p.F733S | Missense Mutation (SNP) | VAF 105/234 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV57208783; called by muse, mutect2, varscan2
- UPF3B | c.889A>C p.K297Q (on ENST00000276201 / NM_080632.3; = p.K284Q on NM_023010.3) | Missense Mutation (SNP) | VAF 303/738 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); catalogued as COSV52230066; called by muse, mutect2, varscan2
- USP11 | c.2887A>T p.N963Y (on ENST00000218348; = p.N920Y on NM_001371072.1) | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.758); catalogued as COSV54473720; called by muse, mutect2, varscan2
- USP13 | c.2320A>G p.S774G | Missense Mutation (SNP) | VAF 162/405 reads (40%) | SIFT tolerated (0.26); PolyPhen benign (0.006); catalogued as rs1050804428, COSV55865730; called by muse, mutect2, varscan2
- USP25 | c.1696T>C p.L566= | Splice Region (SNP) | VAF 70/168 reads (42%) | catalogued as COSV53484310; called by muse, mutect2, varscan2
- USP28 | c.2415A>T p.E805D | Missense Mutation (SNP) | VAF 67/189 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV50162901; called by muse, mutect2, varscan2
- VSTM4 | c.772A>G p.K258E | Missense Mutation (SNP) | VAF 34/89 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.98); catalogued as rs1168645509, COSV60526371; called by muse, mutect2, varscan2
- WBP1 | c.552del p.H185Ifs*10 | Frame Shift Del (DEL) | VAF 19/56 reads (34%) | catalogued as rs773064295, COSV51967888; called by mutect2, pindel, varscan2
- WDR5 | c.649G>A p.V217M | Missense Mutation (SNP) | VAF 33/187 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs200878397, COSV62273022; called by muse, mutect2, varscan2
- XIRP2 | c.331dup p.S111Ffs*5 | Frame Shift Ins (INS) | VAF 110/322 reads (34%) | catalogued as rs35329594; called by mutect2, pindel, varscan2
- ZBTB38 | c.3179A>G p.H1060R | Missense Mutation (SNP) | VAF 50/130 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58541686; called by muse, mutect2, varscan2
- ZBTB47 | c.1748A>G p.E583G | Missense Mutation (SNP) | VAF 11/233 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99233855; called by muse, mutect2
- ZBTB7B | c.134A>G p.Y45C (on ENST00000292176; = p.Y79C on NM_001252406.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV52692618; called by muse, mutect2, varscan2
- ZC3H12B | c.1606A>G p.K536E | Missense Mutation (SNP) | VAF 59/121 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV59048009; called by muse, mutect2, varscan2
- ZC3H18 | c.379G>T p.E127* | Nonsense Mutation (SNP) | VAF 58/121 reads (48%) | catalogued as COSV56324636; called by muse, mutect2, varscan2
- ZCCHC2 | c.3425A>T p.Y1142F | Missense Mutation (SNP) | VAF 98/228 reads (43%) | SIFT tolerated (0.17); PolyPhen benign (0.167); catalogued as COSV54037739; called by muse, mutect2, varscan2
- ZFC3H1 | c.3545A>G p.D1182G | Missense Mutation (SNP) | VAF 141/378 reads (37%) | SIFT tolerated (0.15); PolyPhen benign (0.014); catalogued as COSV66432557; called by muse, mutect2, varscan2
- ZFP37 | c.482del p.N161Ifs*24 | Frame Shift Del (DEL) | VAF 42/107 reads (39%) | catalogued as rs563751025; called by mutect2, varscan2
- ZGRF1 | c.2312dup p.H772Afs*13 | Frame Shift Ins (INS) | VAF 64/208 reads (31%) | catalogued as rs772299653; called by mutect2, pindel, varscan2
- ZHX1 | c.2269C>T p.R757C | Missense Mutation (SNP) | VAF 116/250 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.425); catalogued as rs747135351, COSV52876504; called by muse, mutect2, varscan2
- ZNF200 | c.205A>G p.T69A | Missense Mutation (SNP) | VAF 15/214 reads (7%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.175); catalogued as COSV101205186; called by muse, mutect2
- ZNF251 | c.83A>T p.E28V | Missense Mutation (SNP) | VAF 36/81 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV52957403; called by muse, mutect2, varscan2
- ZNF254 | c.1339T>C p.S447P | Missense Mutation (SNP) | VAF 56/156 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.671); catalogued as COSV61642525; called by muse, mutect2, varscan2
- ZNF263 | c.1631_1632dup p.L545Dfs*12 | Frame Shift Ins (INS) | VAF 21/115 reads (18%) | catalogued as rs763274759; called by mutect2, varscan2
- ZNF408 | c.407G>A p.G136D | Missense Mutation (SNP) | VAF 80/238 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.684); catalogued as COSV61238148; called by muse, mutect2, varscan2
- ZNF521 | c.3916A>C p.M1306L | Missense Mutation (SNP) | VAF 40/124 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV64126936; called by muse, varscan2
- ZNF646 | c.1991G>A p.R664H | Missense Mutation (SNP) | VAF 41/89 reads (46%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.972); catalogued as rs142395653; called by muse, mutect2, varscan2
- ZNF71 | c.765G>A p.M255I | Missense Mutation (SNP) | VAF 25/49 reads (51%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV60147832; called by muse, mutect2, varscan2
- ZNF711 | c.1439A>G p.Y480C | Missense Mutation (SNP) | VAF 110/277 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as COSV52154292; called by muse, mutect2, varscan2
- ZNF93 | c.635A>G p.Y212C | Missense Mutation (SNP) | VAF 29/94 reads (31%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as rs201606871; called by muse, mutect2, varscan2
- ZRANB3 | c.1597dup p.R533Kfs*8 | Frame Shift Ins (INS) | VAF 66/180 reads (37%) | catalogued as rs765112091; called by mutect2, varscan2
- ABTB2 | c.1666T>C p.S556P | Missense Mutation (SNP) | VAF 171/383 reads (45%) | SIFT tolerated (0.32); PolyPhen benign (0.009); called by muse, varscan2
- ACTL8 | c.290dup p.V98Cfs*23 | Frame Shift Ins (INS) | VAF 15/52 reads (29%) | called by mutect2, pindel, varscan2
- ADAMTS6 | c.261dup p.K88* | Frame Shift Ins (INS) | VAF 103/265 reads (39%) | called by mutect2, varscan2
- ANKRD30A | c.1676dup p.D560Gfs*3 (on ENST00000611781; = p.D504Gfs*3 on NM_052997.2) | Frame Shift Ins (INS) | VAF 127/644 reads (20%) | called by mutect2, pindel, varscan2
- AP1S2 | c.338dup p.L113Ffs*3 | Frame Shift Ins (INS) | VAF 114/327 reads (35%) | called by mutect2, pindel, varscan2
- ARHGAP21 | c.1756del p.I586Ffs*5 | Frame Shift Del (DEL) | VAF 40/75 reads (53%) | called by mutect2, pindel, varscan2
- ARHGAP35 | c.3346dup p.I1116Nfs*20 | Frame Shift Ins (INS) | VAF 43/112 reads (38%) | called by mutect2, pindel, varscan2
- ASCC3 | c.5145dup p.F1716Ifs*4 | Frame Shift Ins (INS) | VAF 16/45 reads (36%) | called by mutect2, pindel, varscan2
- ATF7IP | c.959dup p.N320Kfs*4 | Frame Shift Ins (INS) | VAF 62/174 reads (36%) | called by mutect2, varscan2
- ATP13A5 | c.3055dup p.S1019Ffs*25 | Frame Shift Ins (INS) | VAF 97/274 reads (35%) | called by mutect2, pindel, varscan2
- AXIN1 | c.1790dup p.V598Gfs*13 | Frame Shift Ins (INS) | VAF 27/82 reads (33%) | called by mutect2, pindel, varscan2
- BAZ2B | c.6210-16_6232del p.X2070_splice | Splice Site (DEL) | VAF 14/108 reads (13%) | called by mutect2, pindel
- BICC1 | c.1696dup p.I566Nfs*44 | Frame Shift Ins (INS) | VAF 38/98 reads (39%) | called by mutect2, varscan2
- CASP8 | c.1419dup p.L474Tfs*6 (on ENST00000432109 / NM_033355.3; = p.L491Tfs*6 on NM_001228.4) | Frame Shift Ins (INS) | VAF 136/357 reads (38%) | called by mutect2, varscan2
- CCDC181 | c.1399dup p.M467Nfs*12 (on ENST00000367806 / NM_001300969.1; = p.M466Nfs*12 on NM_021179.2) | Frame Shift Ins (INS) | VAF 148/423 reads (35%) | called by mutect2, pindel, varscan2
- CDKL5 | c.2635dup p.L879Pfs*31 | Frame Shift Ins (INS) | VAF 100/284 reads (35%) | called by mutect2, pindel, varscan2
- CECR2 | c.939A>T p.K313N (on ENST00000342247 / NM_001290047.2; = p.K150N on NM_001290046.1) | Missense Mutation (SNP) | VAF 60/156 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.157); called by muse, mutect2
- CEP290 | c.5115dup p.S1706Ifs*2 | Frame Shift Ins (INS) | VAF 298/833 reads (36%) | called by mutect2, pindel, varscan2
- CEP78 | c.2011_2013del p.E671del (on ENST00000424347 / NM_001349840.2; = p.E672del on NM_032171.3) | In Frame Del (DEL) | VAF 77/252 reads (31%) | called by pindel, varscan2
- COL4A6 | c.1802dup p.L603Vfs*7 | Frame Shift Ins (INS) | VAF 47/134 reads (35%) | called by mutect2, pindel, varscan2
- COL5A3 | c.4052del p.P1351Lfs*42 | Frame Shift Del (DEL) | VAF 14/37 reads (38%) | called by mutect2, pindel, varscan2
- CSMD3 | c.10920dup p.A3641Cfs*13 (on ENST00000297405 / NM_001363185.1; = p.A3472Cfs*13 on NM_052900.3) | Frame Shift Ins (INS) | VAF 81/181 reads (45%) | called by mutect2, varscan2
- CUL5 | c.1694dup p.N565Kfs*3 | Frame Shift Ins (INS) | VAF 62/144 reads (43%) | called by mutect2, varscan2
- CXXC4 | c.1041dup p.P348Tfs*14 | Frame Shift Ins (INS) | VAF 47/114 reads (41%) | called by mutect2, pindel, varscan2
- CYFIP2 | c.389G>A p.R130H | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.848); called by muse, mutect2, varscan2
- DDX27 | c.1656dup p.R553Afs*19 | Frame Shift Ins (INS) | VAF 33/101 reads (33%) | called by mutect2, pindel, varscan2
- DOCK7 | c.886-3dup | Splice Region (INS) | VAF 54/145 reads (37%) | called by mutect2, pindel, varscan2
- DST | c.19093dup p.T6365Nfs*23 (on ENST00000361203 / NM_001374722.1; = p.T4062Nfs*23 on NM_015548.5) | Frame Shift Ins (INS) | VAF 117/366 reads (32%) | called by mutect2, pindel, varscan2
- DYNC1H1 | c.11241dup p.S3748Ifs*16 | Frame Shift Ins (INS) | VAF 84/240 reads (35%) | called by mutect2, pindel, varscan2
- EGFLAM | c.1096_1097dup p.S367Afs*32 | Frame Shift Ins (INS) | VAF 42/108 reads (39%) | called by mutect2, varscan2
- FAM111B | c.1321dup p.M441Nfs*18 | Frame Shift Ins (INS) | VAF 52/135 reads (39%) | called by mutect2, pindel, varscan2
- FAT1 | c.377dup p.N126Kfs*3 | Frame Shift Ins (INS) | VAF 53/300 reads (18%) | called by mutect2, varscan2
- FBN1 | c.4204dup p.C1402Lfs*5 | Frame Shift Ins (INS) | VAF 89/256 reads (35%) | called by mutect2, pindel, varscan2
- FERMT3 | c.1528dup p.R510Pfs*105 (on ENST00000279227 / NM_178443.3; = p.R506Pfs*105 on NM_031471.6 and 3 other RefSeq transcripts) | Frame Shift Ins (INS) | VAF 12/22 reads (55%) | called by mutect2, varscan2
- FILIP1L | c.1072del p.I358Sfs*23 (on ENST00000354552 / NM_182909.3; = p.I118Sfs*23 on NM_014890.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 58/465 reads (12%) | called by mutect2, pindel, varscan2
- FMR1 | c.455dup p.A153Gfs*10 | Frame Shift Ins (INS) | VAF 118/331 reads (36%) | called by pindel, varscan2
- FOXD4 | c.499dup p.R167Pfs*31 | Frame Shift Ins (INS) | VAF 9/30 reads (30%) | called by mutect2, pindel, varscan2
- FRA10AC1 | c.264T>A p.Y88* | Nonsense Mutation (SNP) | VAF 144/548 reads (26%) | called by muse, mutect2
- GNS | c.943dup p.E315Gfs*31 | Frame Shift Ins (INS) | VAF 112/375 reads (30%) | called by mutect2, pindel, varscan2
- GPR62 | c.1037A>G p.E346G | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.13); PolyPhen benign (0.007); called by muse, mutect2
- HIVEP2 | c.618dup p.H207Tfs*38 | Frame Shift Ins (INS) | VAF 97/283 reads (34%) | called by mutect2, pindel, varscan2
- HOXA1 | c.373dup p.Q125Pfs*53 | Frame Shift Ins (INS) | VAF 26/93 reads (28%) | called by mutect2, pindel, varscan2
- INPP4B | c.1505dup p.V503Sfs*15 | Frame Shift Ins (INS) | VAF 143/393 reads (36%) | called by mutect2, pindel, varscan2
- KBTBD7 | c.215dup p.G73Wfs*66 | Frame Shift Ins (INS) | VAF 26/73 reads (36%) | called by mutect2, pindel, varscan2
- KCNC1 | c.1370dup p.K458Efs*16 | Frame Shift Ins (INS) | VAF 25/60 reads (42%) | called by mutect2, varscan2
- KCNJ13 | c.494dup p.N165Kfs*10 | Frame Shift Ins (INS) | VAF 58/192 reads (30%) | called by mutect2, pindel, varscan2
- KCNN3 | c.334_335dup p.S113Lfs*64 | Frame Shift Ins (INS) | VAF 38/164 reads (23%) | called by mutect2, varscan2
- KDM6A | c.3679dup p.W1227Lfs*24 | Frame Shift Ins (INS) | VAF 186/602 reads (31%) | called by mutect2, pindel, varscan2
- KIAA0586 | c.2372del p.K791Rfs*14 (on ENST00000619416 / NM_001244190.2; = p.K730Rfs*14 on NM_014749.5) | Frame Shift Del (DEL) | VAF 43/137 reads (31%) | called by pindel, varscan2
- KLC4 | c.453dup p.Q152Afs*6 | Frame Shift Ins (INS) | VAF 47/116 reads (41%) | called by mutect2, pindel, varscan2
- KRCC1 | c.710dup p.K238Efs*35 | Frame Shift Ins (INS) | VAF 153/455 reads (34%) | called by mutect2, pindel, varscan2
- LARS1 | c.987dup p.A330Sfs*21 (on ENST00000394434 / NM_020117.11; = p.A303Sfs*21 on NM_016460.3) | Frame Shift Ins (INS) | VAF 122/365 reads (33%) | called by mutect2, pindel, varscan2
- MAP1A | c.8245dup p.E2749Gfs*12 | Frame Shift Ins (INS) | VAF 19/48 reads (40%) | called by mutect2, pindel, varscan2
- MAP7D3 | c.204del p.K68Nfs*4 | Frame Shift Del (DEL) | VAF 241/720 reads (33%) | called by mutect2, pindel, varscan2
- MRC2 | c.2815dup p.D939Gfs*37 | Frame Shift Ins (INS) | VAF 15/36 reads (42%) | called by mutect2, pindel, varscan2
- MROH2B | c.4295dup p.S1433Efs*22 | Frame Shift Ins (INS) | VAF 110/333 reads (33%) | called by mutect2, pindel, varscan2
- MRPL28 | c.523dup p.Q175Pfs*39 | Frame Shift Ins (INS) | VAF 12/20 reads (60%) | called by mutect2, varscan2
- MYO19 | c.2723A>G p.Q908R (on ENST00000614623 / NM_001163735.1; = p.Q708R on NM_025109.5) | Missense Mutation (SNP) | VAF 37/84 reads (44%) | SIFT tolerated (0.39); PolyPhen benign (0); called by muse, mutect2, varscan2
- MYO9A | c.2372dup p.N791Kfs*4 | Frame Shift Ins (INS) | VAF 66/170 reads (39%) | called by mutect2, varscan2
- NCOA4 | c.787A>G p.K263E | Missense Mutation (SNP) | VAF 22/87 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.341); called by muse, mutect2, varscan2
- NIPBL | c.453dup p.S152Lfs*21 | Frame Shift Ins (INS) | VAF 132/360 reads (37%) | called by mutect2, pindel, varscan2
- NPTX2 | c.485T>C p.L162P | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- PCDH9 | c.339dup p.E114* | Frame Shift Ins (INS) | VAF 68/121 reads (56%) | called by mutect2, pindel, varscan2
- POLR2A | c.1585dup p.Q529Pfs*31 | Frame Shift Ins (INS) | VAF 72/195 reads (37%) | called by mutect2, pindel, varscan2
- POU3F4 | c.709G>T p.A237S | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PPIG | c.36del p.F12Lfs*115 | Frame Shift Del (DEL) | VAF 184/436 reads (42%) | called by mutect2, varscan2
- RAB31 | c.509dup p.L170Ffs*5 | Frame Shift Ins (INS) | VAF 54/150 reads (36%) | called by mutect2, pindel, varscan2
- RUBCN | c.2096A>G p.Q699R | Missense Mutation (SNP) | VAF 6/94 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- SEC31A | c.2667dup p.S890Vfs*20 (on ENST00000355196 / NM_001318120.1; = p.S851Vfs*20 on NM_016211.4) | Frame Shift Ins (INS) | VAF 25/68 reads (37%) | called by mutect2, pindel, varscan2
- SIN3A | c.1976dup p.T660Hfs*7 | Frame Shift Ins (INS) | VAF 59/155 reads (38%) | called by mutect2, pindel, varscan2
- SLC12A1 | c.419dup p.N141Efs*10 | Frame Shift Ins (INS) | VAF 23/64 reads (36%) | called by mutect2, pindel, varscan2
- SLCO5A1 | c.1485del p.K495Nfs*2 | Frame Shift Del (DEL) | VAF 61/176 reads (35%) | called by mutect2, pindel, varscan2
- SMAD7 | c.626del p.P209Lfs*115 | Frame Shift Del (DEL) | VAF 50/116 reads (43%) | called by mutect2, varscan2
- SUCLG1 | c.854dup p.I286Hfs*27 | Frame Shift Ins (INS) | VAF 29/157 reads (18%) | called by mutect2, pindel, varscan2
- TNS4 | c.163G>C p.A55P | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.406); called by muse, mutect2, varscan2
- TOE1 | c.357dup p.V120Sfs*41 | Frame Shift Ins (INS) | VAF 120/339 reads (35%) | called by mutect2, pindel, varscan2
- TRAF3 | c.854del p.N285Tfs*38 | Frame Shift Del (DEL) | VAF 62/185 reads (34%) | called by mutect2, pindel, varscan2
- TRRAP | c.9569A>G p.Q3190R (on ENST00000359863 / NM_001244580.1; = p.Q3161R on NM_003496.3) | Missense Mutation (SNP) | VAF 48/118 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2
- TTC33 | c.559del p.S187Vfs*7 | Frame Shift Del (DEL) | VAF 164/429 reads (38%) | called by mutect2, pindel, varscan2
- TUBB2A | c.422dup p.G142Rfs*57 | Frame Shift Ins (INS) | VAF 16/101 reads (16%) | called by mutect2, varscan2
- TXLNA | c.281dup p.G96Rfs*8 | Frame Shift Ins (INS) | VAF 18/51 reads (35%) | called by mutect2, pindel, varscan2
- UNC45A | c.48del p.A18Pfs*85 | Frame Shift Del (DEL) | VAF 9/17 reads (53%) | called by mutect2, varscan2
- WDR61 | c.13-3dup | Splice Region (INS) | VAF 95/277 reads (34%) | called by mutect2, pindel, varscan2
- XIRP2 | c.1010dup p.N337Kfs*9 (on ENST00000628543; = p.N512Kfs*9 on NM_152381.6) | Frame Shift Ins (INS) | VAF 24/72 reads (33%) | called by mutect2, pindel, varscan2
- ZBTB38 | c.1651dup p.T551Nfs*9 | Frame Shift Ins (INS) | VAF 42/92 reads (46%) | called by mutect2, varscan2
- ZNF292 | c.3938dup p.N1314* | Frame Shift Ins (INS) | VAF 42/132 reads (32%) | called by mutect2, pindel, varscan2
- ZNF582 | c.922G>A p.E308K | Missense Mutation (SNP) | VAF 43/95 reads (45%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZSWIM2 | c.20A>T p.K7M | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); called by muse, mutect2
- ACACB | c.6966A>G p.A2322= | Silent (SNP) | VAF 13/36 reads (36%) | catalogued as rs547306258, COSV58134574; called by muse, mutect2, varscan2
- ACO1 | c.1260T>C p.T420= | Silent (SNP) | VAF 69/195 reads (35%) | catalogued as COSV59379875; called by muse, mutect2, varscan2
- ACOT8 | c.672C>T p.C224= | Silent (SNP) | VAF 17/40 reads (43%) | catalogued as COSV54168994; called by muse, mutect2, varscan2
- ACSL3 | c.1959A>G p.E653= | Silent (SNP) | VAF 15/421 reads (4%) | catalogued as COSV100657806; called by muse, mutect2
- ACTRT2 | c.426G>A p.A142= | Silent (SNP) | VAF 20/43 reads (47%) | catalogued as rs751900024, COSV65759376; called by muse, mutect2, varscan2
- ADAMTSL1 | c.4332G>A p.T1444= | Silent (SNP) | VAF 80/179 reads (45%) | catalogued as rs566582553, COSV65876738; called by muse, mutect2, varscan2
- ADAR | c.2262C>T p.H754= | Silent (SNP) | VAF 39/112 reads (35%) | catalogued as rs779685414, COSV52715419; called by muse, mutect2, varscan2
- ADRA2B | c.1117C>T p.L373= | Silent (SNP) | VAF 40/132 reads (30%) | catalogued as COSV69787517; called by muse, mutect2, varscan2
- AGBL1 | c.1284A>G p.L428= | Silent (SNP) | VAF 52/113 reads (46%) | catalogued as COSV66858364; called by muse, mutect2, varscan2
- ALOX5 | c.1038C>T p.Y346= | Silent (SNP) | VAF 46/109 reads (42%) | catalogued as rs371711392; called by muse, mutect2, varscan2
- AMER3 | c.285C>T p.H95= | Silent (SNP) | VAF 4/23 reads (17%) | catalogued as rs1000607451; called by muse, mutect2
- ANGPT2 | c.1041T>C p.G347= | Silent (SNP) | VAF 106/293 reads (36%) | catalogued as COSV57336948; called by muse, varscan2
- ANK1 | c.3039C>T p.N1013= | Silent (SNP) | VAF 45/93 reads (48%) | catalogued as rs111620878; called by muse, mutect2, varscan2
- ARHGAP21 | c.5442C>T p.S1814= | Silent (SNP) | VAF 141/181 reads (78%) | catalogued as rs529447756, COSV57605725; called by muse, mutect2, varscan2
- ARHGAP29 | c.2073T>C p.C691= | Silent (SNP) | VAF 108/274 reads (39%) | catalogued as COSV53111548; called by muse, mutect2, varscan2
- ARID3B | c.1431A>G p.R477= (on ENST00000622429 / NM_001307939.1; = p.R476= on NM_006465.4) | Silent (SNP) | VAF 31/62 reads (50%) | catalogued as COSV60557665; called by muse, mutect2, varscan2
- ARMH4 | c.1917T>C p.D639= | Silent (SNP) | VAF 335/787 reads (43%) | catalogued as rs1193061960, COSV50764479; called by muse, mutect2, varscan2
- ASZ1 | c.1344T>C p.S448= | Silent (SNP) | VAF 144/349 reads (41%) | catalogued as COSV52912868; called by muse, mutect2, varscan2
- BIRC6 | c.5298T>C p.A1766= | Silent (SNP) | VAF 176/400 reads (44%) | catalogued as rs760068526, COSV70199228; called by muse, mutect2, varscan2
- BTD | c.1290T>C p.H430= | Silent (SNP) | VAF 104/233 reads (45%) | catalogued as COSV57729131; called by muse, mutect2, varscan2
- BUB1 | c.2592A>G p.L864= | Silent (SNP) | VAF 11/299 reads (4%) | catalogued as COSV100240735; called by muse, mutect2
- C5AR2 | c.573C>T p.G191= | Silent (SNP) | VAF 48/86 reads (56%) | catalogued as rs201038011, COSV57256262; called by muse, mutect2, varscan2
- CACNA1B | c.4257C>T p.F1419= | Silent (SNP) | VAF 296/663 reads (45%) | called by muse, mutect2
- CALML5 | c.270C>T p.F90= | Silent (SNP) | VAF 9/30 reads (30%) | catalogued as rs1205523647, COSV100981226; called by muse, mutect2
- CAMSAP1 | c.3372G>A p.T1124= | Silent (SNP) | VAF 41/88 reads (47%) | catalogued as rs373183989, COSV56720883; called by muse, mutect2, varscan2
- CAPN6 | c.561G>T p.V187= | Silent (SNP) | VAF 86/231 reads (37%) | catalogued as COSV60694991; called by muse, mutect2, varscan2
- CATSPERG | c.3456C>T p.A1152= | Silent (SNP) | VAF 54/111 reads (49%) | catalogued as rs142157540; called by muse, mutect2, varscan2
- CCDC102B | c.141T>C p.H47= | Silent (SNP) | VAF 48/132 reads (36%) | catalogued as COSV60141763; called by muse, mutect2, varscan2
- CCDC163 | c.54T>C p.T18= | Silent (SNP) | VAF 83/304 reads (27%) | called by muse, mutect2, varscan2
- CDH5 | c.2175C>T p.Y725= | Silent (SNP) | VAF 25/54 reads (46%) | catalogued as COSV58517437; called by muse, mutect2, varscan2
- CLPP | c.519C>T p.S173= | Silent (SNP) | VAF 13/40 reads (33%) | catalogued as COSV55536597; called by muse, mutect2, varscan2
- COL21A1 | c.2268G>A p.V756= | Silent (SNP) | VAF 60/155 reads (39%) | catalogued as COSV55162628; called by muse, mutect2, varscan2
- CUL1 | c.1671A>G p.S557= | Silent (SNP) | VAF 66/162 reads (41%) | catalogued as COSV57388625; called by muse, mutect2, varscan2
- CUL3 | c.231A>C p.L77= | Silent (SNP) | VAF 139/336 reads (41%) | catalogued as COSV52364761; called by muse, mutect2, varscan2
- CXCR1 | c.330C>T p.C110= | Silent (SNP) | VAF 102/248 reads (41%) | catalogued as COSV55281908; called by muse, mutect2, varscan2
- CYFIP1 | c.975C>T p.Y325= | Silent (SNP) | VAF 11/176 reads (6%) | catalogued as rs781319942; called by muse, mutect2
- DIS3L | c.1833A>G p.K611= (on ENST00000319212 / NM_001143688.3; = p.K528= on NM_133375.5 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 80/195 reads (41%) | catalogued as COSV59912295; called by muse, mutect2, varscan2
- DNAH9 | c.2433G>C p.V811= | Silent (SNP) | VAF 98/238 reads (41%) | catalogued as COSV52349502; called by muse, mutect2, varscan2
- DNAJC11 | c.996G>A p.G332= | Silent (SNP) | VAF 51/109 reads (47%) | catalogued as COSV53786716; called by muse, mutect2, varscan2
- DNAJC21 | c.336T>C p.R112= | Silent (SNP) | VAF 212/507 reads (42%) | catalogued as COSV57760620; called by muse, mutect2, varscan2
- DOCK2 | c.1536A>G p.R512= | Silent (SNP) | VAF 154/412 reads (37%) | catalogued as COSV56958627; called by muse, mutect2, varscan2
- EBF1 | c.336T>C p.L112= | Silent (SNP) | VAF 63/169 reads (37%) | catalogued as COSV58178582; called by muse, mutect2, varscan2
- EIF5AL1 | c.345T>C p.P115= | Silent (SNP) | VAF 113/283 reads (40%) | catalogued as COSV73123034; called by muse, mutect2, varscan2
- FAM53A | c.1002C>T p.T334= | Silent (SNP) | VAF 87/198 reads (44%) | catalogued as COSV57401587; called by muse, mutect2, varscan2
- FAM71D | c.624C>T p.V208= | Silent (SNP) | VAF 82/166 reads (49%) | catalogued as COSV61295475; called by muse, mutect2, varscan2
- FBLN2 | c.2115T>C p.F705= | Silent (SNP) | VAF 118/262 reads (45%) | catalogued as COSV55484436; called by muse, mutect2, varscan2
- FILIP1L | c.1473T>C p.T491= (on ENST00000354552 / NM_182909.3; = p.T251= on NM_014890.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 12/315 reads (4%) | catalogued as COSV100496027; called by muse, mutect2
- FILIP1L | c.864A>G p.A288= (on ENST00000354552 / NM_182909.3; = p.A48= on NM_014890.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 40/490 reads (8%) | catalogued as rs772826886, COSV100496033; called by muse, mutect2
- GDF3 | c.519A>G p.P173= | Silent (SNP) | VAF 43/118 reads (36%) | catalogued as COSV61712460; called by muse, mutect2, varscan2
- GLG1 | c.699A>G p.L233= | Silent (SNP) | VAF 57/206 reads (28%) | catalogued as COSV52667041; called by muse, mutect2, varscan2
- GOLM2 | c.816T>G p.P272= | Silent (SNP) | VAF 102/286 reads (36%) | catalogued as COSV55463406; called by muse, varscan2
- GSPT2 | c.189A>G p.V63= | Silent (SNP) | VAF 21/47 reads (45%) | catalogued as rs1557348798, COSV61214353; called by muse, mutect2, varscan2
- GUCA1C | c.372T>C p.N124= | Silent (SNP) | VAF 126/305 reads (41%) | catalogued as rs777548648, COSV53753135; called by muse, mutect2, varscan2
- HAUS7 | c.594C>T p.D198= | Silent (SNP) | VAF 42/88 reads (48%) | catalogued as COSV57849127; called by muse, mutect2, varscan2
- HEATR5A | c.3168G>A p.Q1056= | Silent (SNP) | VAF 75/177 reads (42%) | catalogued as COSV66340694; called by muse, mutect2, varscan2
- HERC5 | c.2424A>G p.E808= | Silent (SNP) | VAF 130/319 reads (41%) | catalogued as COSV52039894; called by muse, mutect2, varscan2
- ITGA11 | c.1119G>A p.S373= | Silent (SNP) | VAF 56/124 reads (45%) | catalogued as rs377369343; called by muse, mutect2, varscan2
- IZUMO1 | c.987T>C p.L329= | Silent (SNP) | VAF 110/274 reads (40%) | catalogued as rs951432124; called by muse, mutect2
- KRT8 | c.736C>T p.L246= | Silent (SNP) | VAF 13/39 reads (33%) | catalogued as COSV53177270; called by muse, mutect2, varscan2
- LAMB1 | c.3963T>A p.I1321= | Silent (SNP) | VAF 105/259 reads (41%) | catalogued as COSV55964568; called by muse, mutect2, varscan2
- LEAP2 | c.90G>A p.S30= | Silent (SNP) | VAF 95/222 reads (43%) | catalogued as rs556679968, COSV51527802; called by muse, mutect2, varscan2
- LEMD3 | c.2097A>G p.V699= | Silent (SNP) | VAF 119/255 reads (47%) | catalogued as COSV57650402; called by muse, mutect2, varscan2
- LINGO2 | c.1656C>T p.F552= | Silent (SNP) | VAF 90/206 reads (44%) | catalogued as COSV58059686; called by muse, mutect2, varscan2
- LRIG3 | c.3015T>C p.N1005= | Silent (SNP) | VAF 121/278 reads (44%) | catalogued as rs1565612435, COSV57863675; called by muse, mutect2, varscan2
- LRP5 | c.1329G>A p.T443= | Silent (SNP) | VAF 8/31 reads (26%) | catalogued as rs142511038; called by muse, mutect2
- LRRC17 | c.75T>C p.S25= | Silent (SNP) | VAF 34/72 reads (47%) | catalogued as rs1404408609, COSV50864688; called by muse, mutect2, varscan2
- MAPKBP1 | c.1197C>T p.P399= (on ENST00000456763 / NM_001128608.2; = p.P393= on NM_014994.3) | Silent (SNP) | VAF 72/181 reads (40%) | catalogued as rs936137674, COSV52959019, COSV52965086; called by muse, mutect2, varscan2
- MAPRE2 | c.666A>G p.S222= | Silent (SNP) | VAF 87/224 reads (39%) | catalogued as rs140220395; called by muse, mutect2, varscan2
- MARCHF8 | c.813C>T p.S271= | Silent (SNP) | VAF 148/348 reads (43%) | catalogued as rs748794771, COSV60572472; called by muse, mutect2
- MASP2 | c.1356A>G p.K452= | Silent (SNP) | VAF 56/137 reads (41%) | catalogued as COSV53569879; called by muse, mutect2, varscan2
- MIA2 | c.1764T>C p.S588= | Silent (SNP) | VAF 102/263 reads (39%) | catalogued as COSV54483460; called by muse, mutect2, varscan2
- MIS18A | c.552A>G p.Q184= | Silent (SNP) | VAF 63/171 reads (37%) | catalogued as COSV51589229; called by muse, mutect2, varscan2
- MLH1 | c.729T>C p.N243= | Silent (SNP) | VAF 67/173 reads (39%) | catalogued as rs876660573, COSV51618082; ClinVar: likely benign; called by muse, mutect2, varscan2
- MMP3 | c.798C>A p.P266= | Silent (SNP) | VAF 37/85 reads (44%) | catalogued as COSV55406078; called by muse, mutect2, varscan2
- MMS22L | c.1482A>G p.K494= | Silent (SNP) | VAF 132/306 reads (43%) | catalogued as COSV51521099; called by muse, mutect2, varscan2
- MYL4 | c.84C>A p.A28= | Silent (SNP) | VAF 55/140 reads (39%) | catalogued as rs1351846272, COSV61698236; called by muse, mutect2, varscan2
- NBEA | c.1647A>G p.K549= | Silent (SNP) | VAF 159/395 reads (40%) | catalogued as COSV59783933, COSV59810805; called by muse, mutect2, varscan2
- NCOA1 | c.2736A>G p.Q912= | Silent (SNP) | VAF 68/174 reads (39%) | catalogued as rs746848871, COSV56044036; called by muse, mutect2, varscan2
- NRXN1 | c.2718T>G p.P906= | Silent (SNP) | VAF 149/341 reads (44%) | catalogued as COSV58452457; called by muse, mutect2, varscan2
- OBSCN | c.8946C>T p.S2982= | Silent (SNP) | VAF 11/28 reads (39%) | catalogued as rs753985276, COSV52773868; called by muse, mutect2, varscan2
- OR13A1 | c.510C>T p.C170= | Silent (SNP) | VAF 12/24 reads (50%) | catalogued as rs759911354, COSV65572214; called by muse, mutect2
- OR2M4 | c.756C>T p.Y252= | Silent (SNP) | VAF 102/224 reads (46%) | catalogued as rs765816093, COSV60707541; called by muse, mutect2, varscan2
- OR8H3 | c.348C>A p.S116= | Silent (SNP) | VAF 24/474 reads (5%) | catalogued as COSV100538675; called by muse, mutect2
- OTULINL | c.450C>T p.S150= | Silent (SNP) | VAF 148/371 reads (40%) | catalogued as rs114630989; called by muse, mutect2, varscan2
- P2RY1 | c.1107A>G p.G369= | Silent (SNP) | VAF 10/22 reads (45%) | catalogued as COSV59309475; called by muse, mutect2, varscan2
- PARD3 | c.561T>C p.S187= | Silent (SNP) | VAF 85/201 reads (42%) | catalogued as COSV60750086; called by muse, mutect2, varscan2
- PARP1 | c.2901A>C p.V967= | Silent (SNP) | VAF 76/165 reads (46%) | catalogued as COSV64690343; called by muse, mutect2, varscan2
- PATL1 | c.1143T>C p.G381= | Silent (SNP) | VAF 67/188 reads (36%) | catalogued as COSV55689369; called by muse, mutect2, varscan2
- PCDHA10 | c.1041T>C p.P347= | Silent (SNP) | VAF 87/180 reads (48%) | catalogued as COSV56501246; called by muse, mutect2, varscan2
- PCNX4 | c.1512A>G p.V504= (on ENST00000406854 / NM_001330177.2; = p.V270= on NM_022495.5) | Silent (SNP) | VAF 133/285 reads (47%) | catalogued as rs775186557, COSV58304154; called by muse, mutect2, varscan2
- PFKFB2 | c.237T>C p.R79= | Silent (SNP) | VAF 116/289 reads (40%) | catalogued as COSV65548016; called by muse, mutect2, varscan2
- PHF8 | c.633T>C p.F211= (on ENST00000357988 / NM_001184896.1; = p.F175= on NM_015107.3) | Silent (SNP) | VAF 162/347 reads (47%) | catalogued as COSV57681477; called by muse, mutect2, varscan2
- PLIN4 | c.3424T>C p.L1142= (on ENST00000301286; = p.L1157= on NM_001367868.2) | Silent (SNP) | VAF 45/120 reads (38%) | catalogued as rs771944313, COSV56691151; called by muse, mutect2, varscan2
- PPP2R1B | c.1308T>C p.I436= | Silent (SNP) | VAF 34/93 reads (37%) | catalogued as COSV59535523; called by muse, mutect2, varscan2
- PROSER3 | c.1173G>A p.S391= | Silent (SNP) | VAF 8/14 reads (57%) | catalogued as rs1218619275, COSV56553443; called by muse, mutect2, varscan2
- PSMD10 | c.357T>C p.H119= | Silent (SNP) | VAF 181/446 reads (41%) | catalogued as COSV54264124; called by muse, mutect2, varscan2
- PTPN14 | c.1140T>C p.N380= | Silent (SNP) | VAF 62/135 reads (46%) | catalogued as rs375376017; called by muse, mutect2, varscan2
- PTPRE | c.699A>G p.L233= | Silent (SNP) | VAF 84/198 reads (42%) | catalogued as COSV54550968; called by muse, mutect2, varscan2
- PTPRE | c.1896C>T p.A632= | Silent (SNP) | VAF 109/241 reads (45%) | catalogued as rs368063314; called by muse, mutect2, varscan2
- PUM2 | c.1911A>G p.P637= | Silent (SNP) | VAF 123/325 reads (38%) | catalogued as COSV57580620; called by muse, mutect2, varscan2
- PYGB | c.1362T>C p.N454= | Silent (SNP) | VAF 56/320 reads (18%) | catalogued as rs1487102995, COSV53818646; called by muse, mutect2, varscan2
- R3HDM2 | c.1446G>A p.T482= | Silent (SNP) | VAF 185/448 reads (41%) | catalogued as COSV100715699, COSV61288612; called by muse, mutect2, varscan2
- RAB31 | c.63C>T p.S21= | Silent (SNP) | VAF 83/396 reads (21%) | catalogued as COSV71261532; called by muse, mutect2, varscan2
- RAPGEF6 | c.1719A>G p.K573= | Silent (SNP) | VAF 142/387 reads (37%) | catalogued as COSV57246449; called by muse, mutect2, varscan2
- RDH14 | c.978T>C p.D326= | Silent (SNP) | VAF 134/302 reads (44%) | catalogued as COSV67119045; called by muse, mutect2, varscan2
- RERE | c.306T>C p.D102= | Silent (SNP) | VAF 196/465 reads (42%) | catalogued as COSV61942049; called by muse, mutect2, varscan2
- RESF1 | c.2223A>G p.V741= | Silent (SNP) | VAF 58/158 reads (37%) | catalogued as COSV57022075; called by muse, mutect2, varscan2
- RFX3 | c.288T>G p.T96= | Silent (SNP) | VAF 96/226 reads (42%) | catalogued as rs764392006, COSV56515171; called by muse, mutect2, varscan2
- RRAGB | c.1032T>C p.S344= (on ENST00000262850 / NM_016656.4; = p.S316= on NM_006064.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 115/258 reads (45%) | catalogued as COSV53329642; called by muse, mutect2, varscan2
- RYR1 | c.9441C>T p.I3147= | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as rs376129203; called by muse, mutect2, varscan2
- RYR2 | c.6738G>A p.S2246= | Silent (SNP) | VAF 83/237 reads (35%) | catalogued as rs368207198, COSV100772413; ClinVar: likely benign; called by muse, mutect2, varscan2
- SACS | c.1185T>C p.C395= | Silent (SNP) | VAF 130/359 reads (36%) | catalogued as COSV66539849; called by muse, mutect2, varscan2
- SAMD4B | c.504A>G p.S168= | Silent (SNP) | VAF 8/24 reads (33%) | catalogued as COSV58751491; called by muse, mutect2, varscan2
- SBNO2 | c.99C>T p.A33= | Silent (SNP) | VAF 97/207 reads (47%) | catalogued as rs775145865, COSV62320621; called by muse, mutect2, varscan2
- SENP5 | c.378T>C p.S126= | Silent (SNP) | VAF 33/78 reads (42%) | catalogued as COSV60207520; called by muse, mutect2, varscan2
- SHROOM3 | c.4938T>C p.S1646= | Silent (SNP) | VAF 73/180 reads (41%) | catalogued as COSV56029076; called by muse, mutect2, varscan2
- SIX5 | c.2040A>G p.E680= | Silent (SNP) | VAF 12/30 reads (40%) | catalogued as COSV52178215; called by muse, varscan2
- SLC9A4 | c.1929C>T p.H643= | Silent (SNP) | VAF 107/226 reads (47%) | catalogued as COSV54833815; called by muse, mutect2, varscan2
- SLCO5A1 | c.2343T>C p.S781= | Silent (SNP) | VAF 101/245 reads (41%) | catalogued as COSV52659425; called by muse, mutect2, varscan2
- SLTM | c.2340T>C p.P780= | Silent (SNP) | VAF 125/286 reads (44%) | catalogued as COSV65848850; called by muse, mutect2, varscan2
- SMC4 | c.453A>G p.E151= | Silent (SNP) | VAF 11/341 reads (3%) | catalogued as COSV100424220; called by muse, mutect2
- SON | c.4533A>G p.E1511= | Silent (SNP) | VAF 66/150 reads (44%) | catalogued as COSV51657640; called by muse, mutect2, varscan2
- SP140L | c.372A>G p.A124= | Silent (SNP) | VAF 127/308 reads (41%) | catalogued as rs1450308571, COSV54744004; called by muse, mutect2, varscan2
- STK16 | c.210C>T p.R70= | Silent (SNP) | VAF 85/200 reads (43%) | catalogued as COSV50278201; called by muse, mutect2, varscan2
- STK17A | c.210G>A p.G70= | Silent (SNP) | VAF 45/135 reads (33%) | catalogued as rs1563144628, COSV60047118; called by muse, mutect2, varscan2
- TARS3 | c.1524A>G p.E508= | Silent (SNP) | VAF 55/137 reads (40%) | catalogued as rs750520100, COSV60108082; called by muse, mutect2, varscan2
- TEX10 | c.2229T>C p.I743= | Silent (SNP) | VAF 97/279 reads (35%) | catalogued as COSV66515459; called by muse, mutect2, varscan2
- TEX33 | c.669T>C p.A223= (on ENST00000381821 / NM_001163857.2; = p.A138= on NM_178552.4) | Silent (SNP) | VAF 111/280 reads (40%) | catalogued as COSV67822037; called by muse, mutect2, varscan2
- TG | c.2976C>T p.Y992= | Silent (SNP) | VAF 68/146 reads (47%) | catalogued as rs755103292, COSV55076106; called by muse, mutect2, varscan2
- TGFB2 | c.210C>T p.I70= | Silent (SNP) | VAF 11/36 reads (31%) | catalogued as COSV65109298; called by muse, mutect2, varscan2
- THSD7A | c.630C>T p.C210= | Silent (SNP) | VAF 50/117 reads (43%) | catalogued as rs758497643, COSV70262920; called by muse, mutect2, varscan2
- TLE5 | c.588G>A p.S196= | Silent (SNP) | VAF 9/19 reads (47%) | catalogued as rs376230542; called by muse, mutect2, varscan2
- TMEM178A | c.420G>A p.T140= | Silent (SNP) | VAF 77/176 reads (44%) | catalogued as rs199576215, COSV56141877; called by muse, mutect2, varscan2
- TOP3A | c.246T>A p.V82= | Silent (SNP) | VAF 90/240 reads (38%) | catalogued as COSV58177382; called by muse, varscan2
- TRBV2 | c.40T>C p.L14= | Silent (SNP) | VAF 148/359 reads (41%) | called by muse, mutect2, varscan2
- TRIM9 | c.723C>T p.C241= | Silent (SNP) | VAF 54/145 reads (37%) | catalogued as rs1185253249, COSV53617257, COSV53626027; called by muse, mutect2, varscan2
- UHRF2 | c.1182T>C p.T394= | Silent (SNP) | VAF 87/204 reads (43%) | catalogued as COSV52792778; called by muse, mutect2, varscan2
- WASL | c.1368T>A p.S456= | Silent (SNP) | VAF 74/210 reads (35%) | catalogued as rs1163822467, COSV56133650; called by muse, mutect2, varscan2
- YIPF7 | c.777G>A p.Q259= | Silent (SNP) | VAF 58/109 reads (53%) | catalogued as COSV60656782; called by muse, mutect2, varscan2
- ZBTB18 | c.321T>C p.Y107= | Silent (SNP) | VAF 66/148 reads (45%) | catalogued as COSV62396981; called by muse, mutect2, varscan2
- ZIM3 | c.582C>T p.P194= | Silent (SNP) | VAF 11/366 reads (3%) | called by muse, mutect2
- ZNF138 | c.957T>C p.S319= (on ENST00000307355 / NM_001367572.1; = p.S293= on NM_006524.4) | Silent (SNP) | VAF 24/66 reads (36%) | catalogued as COSV56465158; called by muse, mutect2, varscan2
- ZNF148 | c.2301A>G p.S767= | Silent (SNP) | VAF 49/103 reads (48%) | catalogued as COSV62304594; called by muse, varscan2
- ZNF236 | c.294T>C p.C98= | Silent (SNP) | VAF 169/342 reads (49%) | catalogued as COSV53488269; called by muse, mutect2, varscan2
- ZNF333 | c.1902T>G p.T634= | Silent (SNP) | VAF 76/185 reads (41%) | called by muse, mutect2
- ZNF91 | c.2952T>C p.H984= | Silent (SNP) | VAF 11/198 reads (6%) | catalogued as COSV100321852; called by muse, mutect2
- AC024940.1 | n.3091A>G | RNA (SNP) | VAF 12/395 reads (3%) | catalogued as rs1450236756; called by muse, mutect2
- HELZ2 | c.1731-14T>C | Intron (SNP) | VAF 6/12 reads (50%) | called by muse, mutect2
- LINC01565 | n.1205A>T | RNA (SNP) | VAF 36/87 reads (41%) | catalogued as rs376608349; called by muse, mutect2, varscan2
- PAQR3 | c.-1G>A | 5'UTR (SNP) | VAF 9/20 reads (45%) | catalogued as COSV99784687; called by muse, mutect2, varscan2
- PTK2 | c.2030+2608T>C | Intron (SNP) | VAF 47/115 reads (41%) | catalogued as COSV61785787; called by muse, mutect2, varscan2
- SSPOP | n.4075G>A | RNA (SNP) | VAF 84/196 reads (43%) | catalogued as COSV50487433; called by muse, mutect2, varscan2
- TEX11 | c.-56T>C | 5'UTR (SNP) | VAF 124/302 reads (41%) | catalogued as rs1171647614, COSV65467559; called by muse, mutect2, varscan2
- USP34 | chr2:61186769 ins C | 3'Flank (INS) | VAF 36/153 reads (24%) | catalogued as rs754617838; called by mutect2, pindel, varscan2
